Somatic mutation profile of tumor specimen TCGA-QS-A5YQ-01A (aliquot TCGA-QS-A5YQ-01A-11D-A31U-09) from TCGA case TCGA-QS-A5YQ, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIA; Tumor grade: G1; Age at diagnosis: 55.9 years (20,425 days).
Specimen TCGA-QS-A5YQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 41a2cba6-9437-42d0-9baa-6d1faafda639.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-QS-A5YQ-10A (Blood Derived Normal), aliquot TCGA-QS-A5YQ-10A-01D-A31U-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/562a8b9e-9f84-4b38-ac58-456580eb1ac2

The open-access MAF lists 1,079 somatic variants for this specimen: 852 protein-altering or splice-affecting, 206 silent, 21 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 691, Silent 206, Nonsense Mutation 144, RNA 7, Splice Site 7, Intron 7, Splice Region 6, 3'Flank 3, Nonstop Mutation 2, 5'UTR 2, 3'UTR 2, Frame Shift Ins 1.

Variants (750 of 1,079; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATM | c.829G>T p.E277* | Nonsense Mutation (SNP) | VAF 13/35 reads (37%) | catalogued as rs876660933, COSV53735564, COSV53743058; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CTNNB1 | c.101G>A p.G34E | Missense Mutation (SNP) | VAF 28/47 reads (60%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs28931589, COSV62687976, COSV62688267, COSV62692205; ClinVar: likely pathogenic /  other / pathogenic; called by muse, mutect2, varscan2
- NHS | c.1117C>T p.R373* | Nonsense Mutation (SNP) | VAF 18/34 reads (53%) | catalogued as rs132630322, CM032969, COSV66273052; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 16/43 reads (37%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- POLE | c.857C>G p.P286R | Missense Mutation (SNP) | VAF 6/19 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519943, COSV57673247, COSV57678855; ClinVar: uncertain significance / likely pathogenic / drug response; called by muse, mutect2
- PTEN | c.19G>T p.E7* | Nonsense Mutation (SNP) | VAF 15/40 reads (38%) | catalogued as rs1554890335, COSV64288471, COSV64291810; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.895G>T p.E299* | Nonsense Mutation (SNP) | VAF 15/30 reads (50%) | catalogued as rs1114167674, CM110151, COSV64293312; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SMC1A | c.3557T>C p.V1186A | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs587784419, COSV100447571; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TBL1XR1 | c.1108G>A p.D370N | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.554); catalogued as rs1057517933, CM162314, COSV70501537; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A1BG | c.115C>A p.L39M | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.411); catalogued as COSV54051964; called by muse, mutect2, varscan2
- ABCA12 | c.1312G>A p.E438K (on ENST00000272895 / NM_173076.3; = p.E120K on NM_015657.3) | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as rs562998767, COSV55967677; called by muse, mutect2, varscan2
- ABCA13 | c.3820G>T p.E1274* | Nonsense Mutation (SNP) | VAF 6/15 reads (40%) | catalogued as COSV101330122, COSV101330179; called by muse, mutect2, varscan2
- ABCA5 | c.3892G>T p.E1298* | Nonsense Mutation (SNP) | VAF 7/15 reads (47%) | catalogued as COSV67015797; called by muse, mutect2
- ABCB11 | c.2501T>G p.F834C | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as COSV99792605; called by muse, mutect2, varscan2
- ABCC1 | c.1063G>T p.D355Y | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100579998; called by muse, mutect2, varscan2
- ABCC12 | c.3763G>T p.E1255* | Nonsense Mutation (SNP) | VAF 22/53 reads (42%) | catalogued as COSV100252972, COSV60913101; called by muse, mutect2, varscan2
- ABCD2 | c.388A>C p.K130Q | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.58); PolyPhen benign (0.005); catalogued as COSV100429667; called by muse, mutect2
- ABI3 | c.485G>T p.R162I | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99865712; called by muse, mutect2, varscan2
- AC126283.2 | c.1241G>A p.R414K | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT tolerated (0.65); PolyPhen benign (0.001); catalogued as COSV101144578; called by muse, mutect2, varscan2
- ACBD5 | c.406G>T p.E136* (on ENST00000375888 / NM_001352568.1; = p.E138* on NM_145698.5 and 4 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 19/42 reads (45%) | catalogued as COSV101022443; called by muse, mutect2, varscan2
- ACOXL | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369304472; called by muse, mutect2, varscan2
- ACSBG2 | c.920G>T p.S307I | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.014); catalogued as COSV99397537; called by muse, mutect2, varscan2
- ACSM2B | c.1671A>C p.K557N | Missense Mutation (SNP) | VAF 44/96 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61660186; called by muse, mutect2, varscan2
- ACTR3 | c.1012G>T p.D338Y | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99603834; called by muse, mutect2, varscan2
- ACVR2B | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 7/9 reads (78%) | SIFT tolerated (0.44); PolyPhen benign (0.009); catalogued as rs770339569, COSV61701613; called by muse, mutect2, varscan2
- ADAM28 | c.489G>T p.K163N | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs1563280412, COSV99739291; called by muse, mutect2, varscan2
- ADAMTS20 | c.670G>T p.D224Y | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.099); catalogued as COSV67140102; called by muse, mutect2, varscan2
- ADGRE3 | c.731C>A p.S244Y | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.105); catalogued as COSV99506474; called by muse, mutect2
- ADGRG4 | c.6286G>T p.D2096Y | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); catalogued as COSV54961462, COSV99796142; called by muse, mutect2, varscan2
- ADGRG4 | c.6821C>T p.S2274L | Missense Mutation (SNP) | VAF 31/63 reads (49%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs1272460149, COSV54956046; called by muse, mutect2, varscan2
- ADGRL4 | c.383A>C p.K128T | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.075); catalogued as COSV66060841; called by muse, mutect2, varscan2
- ADGRV1 | c.12829C>T p.R4277* | Nonsense Mutation (SNP) | VAF 8/14 reads (57%) | catalogued as COSV67977934; called by muse, mutect2, varscan2
- ADH1A | c.1109G>T p.R370L | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV99265885; called by muse, mutect2, varscan2
- AFF2 | c.3294T>G p.N1098K | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs782136986, COSV99665261; called by muse, varscan2
- AGGF1 | c.828G>T p.K276N | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV100462091; called by muse, mutect2, varscan2
- AGPAT2 | c.713C>T p.A238V | Missense Mutation (SNP) | VAF 34/81 reads (42%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs200656731, CM031122; called by muse, mutect2, varscan2
- AHNAK | c.9402T>G p.I3134M | Missense Mutation (SNP) | VAF 31/95 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.592); catalogued as COSV99948568; called by muse, mutect2, varscan2
- AHNAK | c.4007A>C p.K1336T | Missense Mutation (SNP) | VAF 37/77 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV99948572; called by muse, mutect2, varscan2
- AIM2 | c.589C>A p.L197M | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as COSV100931118; called by muse, mutect2, varscan2
- AKAP7 | c.449A>G p.E150G | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.48); catalogued as COSV100818814; called by muse, mutect2, varscan2
- AKAP9 | c.2384C>A p.T795N | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as COSV100662714; called by muse, mutect2, varscan2
- AKAP9 | c.3068T>G p.V1023G | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated (0.15); PolyPhen benign (0.026); catalogued as COSV100662716; called by muse, mutect2, varscan2
- ALB | c.1194C>T p.F398= | Splice Region (SNP) | VAF 20/40 reads (50%) | catalogued as rs770952660, COSV55735522, COSV55737469; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALB | c.1681C>T p.P561S | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55738496; called by muse, mutect2, varscan2
- ALG2 | c.1037C>T p.S346L | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs544811110, COSV53059689; called by muse, mutect2, varscan2
- ALG2 | c.446C>A p.S149Y | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs1350412580, COSV53059855; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALOX5 | c.430C>T p.R144* | Nonsense Mutation (SNP) | VAF 10/28 reads (36%) | catalogued as rs1161695683, COSV100980133; called by muse, mutect2, varscan2
- ANK2 | c.10513G>A p.D3505N | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs775014029, COSV52168481; called by muse, varscan2
- ANKHD1-EIF4EBP3 | c.6485C>T p.T2162M | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.642); catalogued as rs768045005, COSV51862852; called by muse, mutect2, varscan2
- ANKRD45 | c.217G>T p.E73* | Nonsense Mutation (SNP) | VAF 10/44 reads (23%) | catalogued as COSV60960494; called by muse, mutect2, varscan2
- ANKZF1 | c.210G>T p.E70D | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV99850722; called by muse, mutect2
- ANO3 | c.373C>T p.R125C | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs1230243991, COSV56792990; called by muse, varscan2
- ANOS1 | c.691G>A p.E231K | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV99391174; called by muse, mutect2, varscan2
- ANXA13 | c.10C>T p.R4C | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT tolerated (0.18); PolyPhen benign (0.333); catalogued as rs367659079, COSV51621713; called by muse, mutect2, varscan2
- AP002512.3 | c.840C>A p.F280L | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.721); catalogued as COSV99688058; called by muse, mutect2, varscan2
- AP3S1 | c.582A>C p.*194Yext*9 | Nonstop Mutation (SNP) | VAF 15/63 reads (24%) | catalogued as COSV100372856; called by muse, mutect2, varscan2
- APCDD1 | c.1267G>A p.E423K | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763105125, COSV100789995; called by muse, mutect2, varscan2
- APPL1 | c.1954G>T p.E652* | Nonsense Mutation (SNP) | VAF 10/47 reads (21%) | catalogued as rs1429184808, COSV55699870, COSV99897215; called by muse, mutect2, varscan2
- AQP9 | c.73G>T p.E25* | Nonsense Mutation (SNP) | VAF 24/43 reads (56%) | catalogued as COSV99583091; called by muse, mutect2, varscan2
- ARHGAP29 | c.863A>C p.K288T | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.298); catalogued as COSV99558599; called by muse, mutect2
- ARHGAP6 | c.1719C>A p.F573L | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV57300344; called by muse, mutect2, varscan2
- ARID4A | c.641G>A p.R214Q | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62165301; called by muse, mutect2, varscan2
- ARMCX1 | c.1182G>T p.E394D | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); catalogued as COSV100863226; called by muse, mutect2, varscan2
- ARSF | c.868C>A p.L290I | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.757); catalogued as COSV100839556; called by muse, mutect2, varscan2
- ASB15 | c.286C>A p.L96M | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.93); catalogued as COSV51924746, COSV99306824; called by muse, mutect2, varscan2
- ASPM | c.7544G>A p.R2515Q | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs751584273, COSV54123850; called by muse, mutect2, varscan2
- ASPM | c.6095G>A p.R2032H | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs149033840, COSV54128644; called by muse, mutect2, varscan2
- ASXL3 | c.7G>T p.D3Y | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.195); catalogued as COSV99325763; called by muse, mutect2, varscan2
- ASZ1 | c.799G>T p.D267Y | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.804); catalogued as rs1466789937, COSV99498082; called by muse, mutect2, varscan2
- ATAD1 | c.647T>G p.F216C | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100058334; called by muse, mutect2, varscan2
- ATAD2B | c.2725G>T p.E909* | Nonsense Mutation (SNP) | VAF 15/34 reads (44%) | catalogued as COSV99478104, COSV99478132; called by muse, mutect2, varscan2
- ATP10B | c.3640T>C p.Y1214H | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100515433; called by muse, mutect2, varscan2
- ATP13A4 | c.2917C>A p.L973I | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.899); catalogued as COSV100710534; called by muse, mutect2, varscan2
- ATP4A | c.2464G>A p.E822K | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); catalogued as COSV52866740; called by muse, mutect2, varscan2
- ATP6V0A4 | c.121A>C p.N41H | Missense Mutation (SNP) | VAF 38/94 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100023353; called by muse, mutect2, varscan2
- BAIAP3 | c.1979C>T p.S660L | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs374379669; called by muse, mutect2, varscan2
- BCAN | c.1850G>T p.R617I | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.737); catalogued as COSV100228301; called by muse, mutect2
- BCL2A1 | c.20G>A p.G7E | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.27); PolyPhen benign (0.115); catalogued as COSV99144352; called by muse, mutect2, varscan2
- BCL7A | c.177A>C p.K59N | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV99947152; called by muse, mutect2, varscan2
- BCL9L | c.2316G>T p.M772I | Missense Mutation (SNP) | VAF 31/60 reads (52%) | SIFT tolerated (0.2); PolyPhen benign (0.373); catalogued as COSV99419716; called by muse, mutect2, varscan2
- BDP1 | c.2626G>T p.E876* | Nonsense Mutation (SNP) | VAF 7/14 reads (50%) | catalogued as COSV100703355; called by muse, mutect2, varscan2
- BMP1 | c.304G>A p.G102R | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.58); PolyPhen benign (0.03); catalogued as COSV100109893; called by muse, mutect2, varscan2
- BMP2K | c.3442G>A p.E1148K | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.912); catalogued as rs754970059, COSV55008366; called by muse, mutect2, varscan2
- BMPER | c.1972C>T p.P658S | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.542); catalogued as COSV99780115; called by muse, mutect2, varscan2
- BRD3 | c.1161C>A p.C387* | Nonsense Mutation (SNP) | VAF 11/35 reads (31%) | catalogued as COSV100325348; called by muse, mutect2, varscan2
- BRINP3 | c.512C>T p.S171L | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as rs765103774, COSV66523080; called by muse, mutect2, varscan2
- BROX | c.221C>A p.S74Y | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.866); catalogued as COSV61799005; called by muse, mutect2, varscan2
- BTN1A1 | c.64C>T p.P22S | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated (0.42); PolyPhen benign (0.005); catalogued as rs1347143023, COSV99764484; called by muse, mutect2, varscan2
- BTRC | c.847G>T p.E283* (on ENST00000370187 / NM_033637.4; = p.E247* on NM_003939.5) | Nonsense Mutation (SNP) | VAF 18/31 reads (58%) | catalogued as COSV100927885; called by muse, mutect2, varscan2
- C10orf88 | c.1030C>A p.H344N | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.544); catalogued as COSV100925033; called by muse, mutect2, varscan2
- C10orf90 | c.2047G>A p.E683K | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.551); catalogued as rs752025882, COSV52949458; called by muse, mutect2, varscan2
- C12orf40 | c.1136G>T p.R379I | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.281); catalogued as COSV100210459; called by muse, mutect2, varscan2
- C16orf46 | c.178G>T p.E60* | Nonsense Mutation (SNP) | VAF 14/42 reads (33%) | catalogued as COSV100215402, COSV55153182; called by muse, mutect2, varscan2
- C1QTNF8 | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.022); catalogued as rs145677284; called by muse, mutect2, varscan2
- C1QTNF9 | c.559C>T p.R187* | Nonsense Mutation (SNP) | VAF 9/37 reads (24%) | catalogued as rs777575333, COSV59656910; called by muse, mutect2, varscan2
- C1orf94 | c.1666G>T p.D556Y (on ENST00000488417 / NM_001134734.2; = p.D366Y on NM_032884.5) | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV100975103; called by muse, mutect2, varscan2
- C2orf78 | c.137C>A p.S46Y | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV101281010; called by muse, mutect2, varscan2
- C3orf20 | c.1732G>T p.E578* | Nonsense Mutation (SNP) | VAF 11/38 reads (29%) | catalogued as COSV99514206, COSV99514310; called by muse, mutect2, varscan2
- C4BPA | c.1794A>C p.*598Yext*40 | Nonstop Mutation (SNP) | VAF 4/26 reads (15%) | catalogued as COSV100891246; called by muse, mutect2
- C6 | c.554A>C p.N185T | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV99667467; called by muse, mutect2, varscan2
- C6 | c.433C>T p.R145C | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as rs267600638, COSV54704649; called by muse, mutect2, varscan2
- CA14 | c.715G>A p.E239K | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.45); PolyPhen benign (0.111); catalogued as COSV99354408, COSV99354452; called by muse, mutect2, varscan2
- CACNB2 | c.785G>T p.R262I (on ENST00000324631 / NM_201596.3; = p.R207I on NM_000724.4) | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.309); catalogued as rs754892849, COSV56611627; called by muse, mutect2, varscan2
- CALCR | c.806T>G p.F269C (on ENST00000649521 / NM_001164737.2; = p.F253C on NM_001742.4) | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100810704; called by muse, mutect2, varscan2
- CAMKK1 | c.1149G>T p.K383N | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as rs868607765, COSV99340440; called by muse, mutect2
- CAMSAP2 | c.3977G>A p.R1326Q (on ENST00000236925 / NM_001297707.2; = p.R1315Q on NM_203459.3) | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT tolerated (0.05); PolyPhen benign (0.413); catalogued as rs146701959; called by muse, mutect2, varscan2
- CAPN6 | c.113C>A p.S38Y | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100136965; called by muse, mutect2, varscan2
- CARS1 | c.405A>G p.P135= | Splice Region (SNP) | VAF 14/39 reads (36%) | catalogued as COSV99543171; called by muse, mutect2, varscan2
- CASP1 | c.611A>C p.K204T (on ENST00000436863 / NM_033292.4; = p.K183T on NM_001223.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.025); catalogued as COSV100782818; called by muse, mutect2, varscan2
- CATSPER1 | c.2141C>T p.A714V | Missense Mutation (SNP) | VAF 20/34 reads (59%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs764683817, COSV56412480; called by muse, mutect2, varscan2
- CCDC138 | c.111T>G p.F37L | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.015); catalogued as rs1443958025, COSV51700466; called by muse, mutect2
- CCDC138 | c.829G>T p.E277* | Nonsense Mutation (SNP) | VAF 18/33 reads (55%) | catalogued as rs752809632, COSV54564084; called by muse, mutect2, varscan2
- CCDC160 | c.493G>T p.E165* | Nonsense Mutation (SNP) | VAF 16/32 reads (50%) | catalogued as COSV100892127; called by muse, mutect2, varscan2
- CCDC173 | c.417A>C p.E139D | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.73); PolyPhen benign (0.071); catalogued as COSV101352364; called by muse, mutect2, varscan2
- CCDC38 | c.1183C>T p.L395F | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV100717761; called by muse, mutect2, varscan2
- CCDC39 | c.1666G>A p.D556N | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as COSV99869995; called by muse, mutect2, varscan2
- CCDC50 | c.997A>G p.K333E (on ENST00000392455 / NM_178335.3; = p.K157E on NM_174908.4) | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.275); catalogued as COSV101165333; called by muse, mutect2, varscan2
- CCDC77 | c.1132C>T p.R378C | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as rs1030728081, COSV53472282, COSV53472571; called by muse, mutect2, varscan2
- CCDC81 | c.1409C>T p.A470V (on ENST00000445632 / NM_001156474.2; = p.A380V on NM_021827.4) | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.039); catalogued as rs765361361, COSV99564629; called by muse, mutect2, varscan2
- CCDC82 | c.92G>T p.R31I | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1322323262, COSV53592385; called by muse, mutect2
- CCDC88A | c.1681G>T p.E561* | Nonsense Mutation (SNP) | VAF 13/27 reads (48%) | catalogued as COSV99710895; called by muse, mutect2, varscan2
- CCNB3 | c.2013C>A p.F671L | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.27); PolyPhen benign (0.043); catalogued as rs781787863, COSV99329462; called by muse, mutect2, varscan2
- CCR8 | c.949A>G p.K317E | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.655); catalogued as COSV100413004, COSV100413140; called by muse, mutect2, varscan2
- CD209 | c.348G>T p.E116D | Missense Mutation (SNP) | VAF 56/178 reads (31%) | SIFT tolerated, low confidence (0.21); PolyPhen possibly damaging (0.771); catalogued as COSV99214213; called by muse, mutect2, varscan2
- CD53 | c.544T>G p.F182V | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.909); catalogued as COSV99602310; called by muse, mutect2, varscan2
- CDC20B | c.698-1G>T p.X233_splice | Splice Site (SNP) | VAF 6/16 reads (38%) | catalogued as COSV99697199; called by muse, varscan2
- CDH19 | c.1876C>A p.L626I | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.681); catalogued as rs1413928670, COSV100051227, COSV50959575; called by muse, mutect2, varscan2
- CDH19 | c.1252G>T p.D418Y | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.863); catalogued as COSV100051925; called by muse, mutect2, varscan2
- CDH26 | c.1901T>A p.F634Y | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.672); catalogued as COSV99722766; called by muse, mutect2
- CDH8 | c.1045A>C p.K349Q | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV100182125; called by muse, mutect2, varscan2
- CDH9 | c.2135T>C p.V712A | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as rs1250585725, COSV99148940; called by muse, mutect2, varscan2
- CDH9 | c.1901C>T p.A634V | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs770288209, COSV99144496, COSV99148956; called by muse, mutect2, varscan2
- CDK5RAP2 | c.2584G>A p.E862K | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs1343728654, COSV62574034; called by muse, mutect2, varscan2
- CENPC | c.299T>C p.V100A | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV99894223; called by muse, mutect2, varscan2
- CENPJ | c.2873G>A p.R958Q | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.048); catalogued as rs1452062416, COSV67882961; called by muse, mutect2, varscan2
- CENPL | c.1018A>C p.I340L | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.55); PolyPhen benign (0.023); catalogued as COSV100616410; called by muse, mutect2, varscan2
- CEP78 | c.517A>C p.K173Q | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99450746; called by muse, mutect2, varscan2
- CETN2 | c.481G>T p.E161* | Nonsense Mutation (SNP) | VAF 7/92 reads (8%) | catalogued as COSV100938676; called by muse, mutect2
- CHD4 | c.3906G>T p.E1302D (on ENST00000357008 / NM_001363606.2; = p.E1315D on NM_001273.5) | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.987); catalogued as COSV100538555; called by muse, mutect2, varscan2
- CHRNA1 | c.1155G>T p.K385N (on ENST00000261007 / NM_001039523.3; = p.K360N on NM_000079.4) | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT tolerated (0.27); PolyPhen benign (0.021); catalogued as COSV53684435, COSV99650570; called by muse, mutect2, varscan2
- CHSY3 | c.1123C>T p.R375W | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs1033562678, COSV59275201; called by muse, mutect2, varscan2
- CIITA | c.2944G>A p.A982T | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.621); catalogued as COSV100162376; called by muse, mutect2, varscan2
- CILK1 | c.838C>T p.R280* | Nonsense Mutation (SNP) | VAF 12/22 reads (55%) | catalogued as COSV100607880; called by muse, mutect2, varscan2
- CKAP2 | c.85A>C p.K29Q | Missense Mutation (SNP) | VAF 15/25 reads (60%) | SIFT deleterious (0.04); PolyPhen benign (0.29); catalogued as COSV99318394; called by muse, mutect2, varscan2
- CLASRP | c.502G>A p.E168K | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0.02); catalogued as rs767334757, COSV99673995; called by muse, mutect2, varscan2
- CLCN1 | c.257C>A p.S86Y | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.061); catalogued as COSV100578303, COSV58373315; called by muse, mutect2, varscan2
- CLDN16 | c.466C>A p.L156I | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0.229); catalogued as COSV99290283; called by muse, mutect2, varscan2
- CLU | c.1090G>A p.E364K | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.6); PolyPhen benign (0.136); catalogued as rs566482024, COSV57068016; called by muse, mutect2, varscan2
- CLUAP1 | c.682C>T p.R228W | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.019); catalogued as rs938197865, COSV100489737; called by muse, mutect2, varscan2
- CMYA5 | c.10718T>G p.F3573C | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV101484214; called by muse, mutect2, varscan2
- CNNM3 | c.1433T>C p.F478S | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100562749; called by muse, mutect2, varscan2
- CNOT1 | c.4295C>A p.S1432* | Nonsense Mutation (SNP) | VAF 10/25 reads (40%) | catalogued as COSV55315174; called by mutect2, varscan2
- CNTLN | c.370G>T p.E124* | Nonsense Mutation (SNP) | VAF 9/52 reads (17%) | catalogued as rs1456302187, COSV52076815, COSV52095991; called by muse, mutect2, varscan2
- CNTLN | c.641A>C p.K214T | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.714); catalogued as COSV99264992; called by muse, mutect2, varscan2
- CNTLN | c.3402A>C p.E1134D | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT tolerated (0.31); PolyPhen benign (0.046); catalogued as COSV99264996; called by muse, mutect2, varscan2
- CNTN1 | c.1718C>T p.A573V | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.4); PolyPhen benign (0.113); catalogued as rs771137056, COSV100751682; called by muse, mutect2, varscan2
- CNTN4 | c.3014C>T p.S1005L | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs753714750, COSV61867614; called by muse, mutect2, varscan2
- CNTNAP2 | c.3993T>G p.I1331M | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100668753; called by muse, mutect2, varscan2
- COA6 | c.232C>A p.Q78K | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.59); PolyPhen benign (0.006); catalogued as COSV100784598; called by muse, mutect2, varscan2
- COL11A1 | c.266T>G p.L89* | Nonsense Mutation (SNP) | VAF 25/53 reads (47%) | catalogued as COSV100617563; called by muse, mutect2, varscan2
- COL5A1 | c.1075G>A p.E359K | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0.025); catalogued as rs769752636, COSV100880226; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL5A3 | c.3913G>A p.A1305T | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs763576120, COSV99319372; called by muse, mutect2, varscan2
- COL6A1 | c.2512G>A p.A838T | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT tolerated (0.42); PolyPhen benign (0.112); catalogued as rs529770550, COSV62613829; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- COL6A5 | c.7357G>T p.E2453* (on ENST00000312481; = p.E2449* on NM_153264.6 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 8/23 reads (35%) | catalogued as COSV55198362, COSV55202876; called by muse, mutect2, varscan2
- COPA | c.1301C>T p.S434L | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as rs769707936, COSV54106407; called by muse, mutect2, varscan2
- CPNE4 | c.422C>T p.S141F | Missense Mutation (SNP) | VAF 18/31 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV70200148; called by muse, mutect2, varscan2
- CRELD1 | c.1084G>A p.E362K | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs774428153, COSV55976257; called by muse, mutect2, varscan2
- CRPPA | c.1211G>T p.R404I (on ENST00000407010 / NM_001368197.1; = p.R354I on NM_001101417.4) | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.36); catalogued as COSV67908601; called by muse, mutect2, varscan2
- CSF3R | c.1121C>A p.S374Y | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); catalogued as COSV58964310; called by muse, mutect2, varscan2
- CSMD1 | c.1865G>A p.R622Q (on ENST00000520002; = p.R621Q on NM_033225.6) | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs1197438135, COSV59387484; called by muse, mutect2, varscan2
- CSMD3 | c.6692G>A p.R2231Q (on ENST00000297405 / NM_001363185.1; = p.R2127Q on NM_052900.3) | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.6); catalogued as rs751658267, COSV52145865, COSV99832218; called by muse, mutect2, varscan2
- CSTF1 | c.500G>A p.R167Q | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99410279; called by muse, mutect2, varscan2
- CTNND1 | c.2233G>T p.E745* (on ENST00000399050 / NM_001085458.2; = p.E739* on NM_001331.3) | Nonsense Mutation (SNP) | VAF 7/19 reads (37%) | catalogued as COSV62382083; called by muse, mutect2, varscan2
- CTSV | c.872C>T p.S291L | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.396); catalogued as rs771264161, COSV52344711; called by muse, mutect2, varscan2
- CUBN | c.3802C>T p.R1268C | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as rs747558831, COSV64713018; called by muse, mutect2, varscan2
- CXCL5 | c.17G>C p.S6T | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.971); catalogued as COSV56019201, COSV99932920; called by muse, mutect2, varscan2
- CXCR1 | c.224A>G p.D75G | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.833); catalogued as COSV99826372; called by muse, mutect2, varscan2
- CXorf56 | c.209A>G p.N70S | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.44); PolyPhen benign (0.117); catalogued as COSV100233440; called by muse, mutect2, varscan2
- CYBRD1 | c.491T>G p.I164S | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated (0.47); PolyPhen benign (0.042); catalogued as COSV100361415; called by muse, mutect2, varscan2
- CYP2C19 | c.727G>T p.D243Y | Missense Mutation (SNP) | VAF 31/84 reads (37%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as COSV100990579, COSV64907233; called by muse, mutect2, varscan2
- CYP2C19 | c.1284C>A p.F428L | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.744); catalogued as COSV100990580; called by muse, varscan2
- DAPK1 | c.2834G>A p.R945Q | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.216); catalogued as rs748494486, COSV63783719; called by muse, mutect2, varscan2
- DAPK3 | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.211); catalogued as COSV100009800; called by muse, mutect2, varscan2
- DCC | c.2882G>A p.R961H | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.487); catalogued as rs776722332, COSV100501723; called by muse, mutect2, varscan2
- DCHS1 | c.9553C>T p.R3185W | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs745894081, COSV100197602; called by muse, mutect2, varscan2
- DCLK2 | c.823C>T p.R275C | Missense Mutation (SNP) | VAF 37/88 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.398); catalogued as COSV56198611; called by muse, mutect2, varscan2
- DCP2 | c.56G>A p.R19Q | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747931440, COSV66616641; called by muse, mutect2, varscan2
- DCX | c.792T>G p.F264L | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.028); catalogued as COSV100576637; called by muse, mutect2, varscan2
- DDHD1 | c.293T>G p.V98G (on ENST00000323669; = p.V329G on NM_030637.3) | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); catalogued as COSV100079806; called by muse, mutect2, varscan2
- DDX20 | c.421G>T p.E141* | Nonsense Mutation (SNP) | VAF 6/11 reads (55%) | catalogued as rs1462330675, COSV63830952; called by muse, mutect2, varscan2
- DEFB128 | c.102G>T p.K34N | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100544455; called by muse, mutect2, varscan2
- DENR | c.113C>A p.S38* | Nonsense Mutation (SNP) | VAF 9/37 reads (24%) | catalogued as COSV99757398; called by muse, mutect2, varscan2
- DEPDC7 | c.441G>T p.E147D (on ENST00000241051 / NM_001077242.2; = p.E138D on NM_139160.2) | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as COSV53808195; called by muse, mutect2, varscan2
- DEUP1 | c.116A>C p.K39T | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV99977404; called by muse, varscan2
- DGKK | c.927G>T p.Q309H | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV101052981; called by muse, mutect2, varscan2
- DHX37 | c.3307G>A p.E1103K | Missense Mutation (SNP) | VAF 16/27 reads (59%) | SIFT deleterious (0.04); PolyPhen benign (0.162); catalogued as COSV100439374; called by muse, mutect2, varscan2
- DIAPH2 | c.2996G>A p.R999Q | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.046); catalogued as rs1569369481, COSV61298200; called by muse, mutect2, varscan2
- DISC1 | c.1158G>T p.E386D | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV54406520; called by mutect2, varscan2
- DISP1 | c.2108G>A p.R703Q | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.679); catalogued as rs752790327, COSV52662040, COSV99451619; called by muse, mutect2, varscan2
- DISP2 | c.825G>T p.E275D | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51119282; called by muse, mutect2, varscan2
- DKK1 | c.439C>T p.R147* | Nonsense Mutation (SNP) | VAF 12/32 reads (38%) | catalogued as rs1372405846, COSV64760610; called by muse, mutect2, varscan2
- DLG2 | c.160G>A p.E54K (on ENST00000650630 / NM_001351274.2; = p.E17K on NM_001142699.3) | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV101072624, COSV65826078; called by muse, mutect2, varscan2
- DMD | c.5899C>T p.R1967* | Nonsense Mutation (SNP) | VAF 15/32 reads (47%) | catalogued as rs128626249, CM087401, CM930194, COSV63737423; ClinVar: conflicting interpretations of pathogenicity / pathogenic; called by muse, mutect2, varscan2
- DMRT2 | c.738G>T p.E246D | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.991); catalogued as COSV99426173; called by muse, mutect2, varscan2
- DMXL2 | c.4525G>T p.E1509* | Nonsense Mutation (SNP) | VAF 14/41 reads (34%) | catalogued as COSV99196799; called by muse, mutect2, varscan2
- DNAH11 | c.4426G>A p.E1476K | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.49); catalogued as rs1188885955, COSV60980346; called by muse, mutect2
- DNAH2 | c.5473A>C p.I1825L | Missense Mutation (SNP) | VAF 16/27 reads (59%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.524); catalogued as COSV101209499; called by muse, mutect2, varscan2
- DNAH2 | c.9186C>T p.A3062= | Splice Region (SNP) | VAF 10/24 reads (42%) | catalogued as rs144786059; called by muse, varscan2
- DNAH3 | c.7400A>C p.N2467T | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.48); PolyPhen benign (0.007); catalogued as COSV99769161; called by muse, mutect2
- DNAH3 | c.6309C>A p.F2103L | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1464593357, COSV54502803, COSV99767066; called by muse, mutect2, varscan2
- DNAH5 | c.12631G>A p.E4211K | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762673561, COSV54204698, COSV54216995; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH5 | c.1420G>A p.E474K | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.052); catalogued as rs886060012, COSV54208276; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH7 | c.7906G>T p.E2636* | Nonsense Mutation (SNP) | VAF 12/40 reads (30%) | catalogued as COSV56789273; called by muse, mutect2, varscan2
- DNAH7 | c.4921C>A p.Q1641K | Missense Mutation (SNP) | VAF 36/101 reads (36%) | SIFT tolerated (0.54); PolyPhen benign (0.313); catalogued as COSV100416368; called by muse, mutect2, varscan2
- DNAH8 | c.9493A>C p.I3165L | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV100546461; called by muse, mutect2, varscan2
- DNAJB4 | c.333C>A p.F111L | Missense Mutation (SNP) | VAF 25/47 reads (53%) | SIFT tolerated (0.08); PolyPhen benign (0.026); catalogued as rs775364732, COSV100883469, COSV66131954; called by muse, mutect2, varscan2
- DNAJB5 | c.325G>A p.D109N | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT tolerated (0.33); PolyPhen benign (0.04); catalogued as rs752945019, COSV56625070; called by muse, mutect2, varscan2
- DNAJB9 | c.589C>A p.H197N | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT tolerated (0.15); PolyPhen benign (0.054); catalogued as COSV99974548; called by muse, mutect2
- DOCK10 | c.6497G>A p.R2166Q | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.009); catalogued as rs371356763; called by muse, mutect2, varscan2
- DOCK2 | c.4786C>T p.R1596* | Nonsense Mutation (SNP) | VAF 20/56 reads (36%) | catalogued as COSV56951180, COSV99914045; called by muse, mutect2, varscan2
- DOCK7 | c.2869C>T p.R957* (on ENST00000635253 / NM_001367561.1; = p.R926* on NM_033407.3) | Nonsense Mutation (SNP) | VAF 16/33 reads (48%) | catalogued as COSV99225296; called by muse, mutect2, varscan2
- DPY19L2 | c.1531A>G p.K511E | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.196); catalogued as COSV100116887; called by muse, mutect2, varscan2
- DSCAML1 | c.128C>G p.A43G | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.588); catalogued as COSV100356586; called by muse, mutect2, varscan2
- DSG2 | c.2842C>T p.P948S | Missense Mutation (SNP) | VAF 14/23 reads (61%) | SIFT tolerated (0.45); PolyPhen benign (0.122); catalogued as COSV99853343; called by muse, mutect2, varscan2
- DSPP | c.2659G>A p.E887K | Missense Mutation (SNP) | VAF 39/101 reads (39%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as rs1441961526, COSV99217676; called by muse, mutect2, varscan2
- DST | c.3971G>T p.S1324I (on ENST00000361203 / NM_001374722.1; = p.S998I on NM_001723.6) | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.791); catalogued as COSV99758325; called by muse, mutect2, varscan2
- DUXA | c.594C>A p.F198L | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.001); catalogued as COSV73729785, COSV73729847; called by muse, mutect2, varscan2
- DYNC1H1 | c.289G>T p.E97* | Nonsense Mutation (SNP) | VAF 6/18 reads (33%) | catalogued as COSV64134772; called by muse, mutect2, varscan2
- DYNC1I2 | c.1121C>T p.P374L | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99784126; called by muse, mutect2, varscan2
- DYNC2H1 | c.3967G>T p.D1323Y | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1179088763, COSV100519151; called by muse, mutect2, varscan2
- DYRK1A | c.630G>T p.M210I | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.304); catalogued as COSV100118114; called by muse, mutect2
- E2F5 | c.373G>T p.E125* | Nonsense Mutation (SNP) | VAF 12/31 reads (39%) | catalogued as COSV99809638; called by muse, mutect2, varscan2
- EBF2 | c.493G>A p.E165K | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.109); catalogued as COSV68775824; called by muse, mutect2, varscan2
- ECT2L | c.2395G>T p.E799* | Nonsense Mutation (SNP) | VAF 8/32 reads (25%) | catalogued as COSV62884259; called by muse, mutect2, varscan2
- EDA | c.343C>A p.P115T | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.029); catalogued as COSV100140962; called by muse, mutect2, varscan2
- EDEM3 | c.329C>A p.S110Y | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as COSV100545523; called by muse, mutect2, varscan2
- EFHB | c.517A>C p.K173Q | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.116); catalogued as COSV99859958; called by muse, mutect2, varscan2
- EHD2 | c.922G>A p.A308T | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.51); catalogued as rs1028265447, COSV99622099; called by muse, mutect2, varscan2
- EIF3I | c.281C>T p.S94L | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); catalogued as COSV100557235; called by muse, mutect2, varscan2
- ELAVL4 | c.458C>T p.S153L | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT deleterious (0.02); PolyPhen benign (0.191); catalogued as rs1175579240, COSV63915417; called by muse, mutect2, varscan2
- ELL2 | c.758C>A p.S253Y | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.397); catalogued as COSV99427693; called by muse, mutect2, varscan2
- ELL2 | c.577C>T p.R193* | Nonsense Mutation (SNP) | VAF 13/52 reads (25%) | catalogued as rs1416098476, COSV52981190; called by muse, mutect2, varscan2
- ELN | c.475C>T p.R159W | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.965); catalogued as rs1273222616, COSV99332883; called by muse, mutect2, varscan2
- EP300 | c.842C>A p.S281* | Nonsense Mutation (SNP) | VAF 9/18 reads (50%) | catalogued as COSV54339708, COSV99609302; called by muse, mutect2, varscan2
- EPG5 | c.6541G>T p.E2181* | Nonsense Mutation (SNP) | VAF 12/32 reads (38%) | catalogued as rs755840290, COSV56347802; called by muse, varscan2
- EPPK1 | c.4654A>G p.T1552A | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as COSV101599908; called by muse, mutect2, varscan2
- EPX | c.872G>T p.C291F | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99836659; called by muse, mutect2, varscan2
- ERICH3 | c.3754G>A p.A1252T | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0.013); catalogued as rs151238210, COSV58609761; called by muse, mutect2, varscan2
- ERICH6 | c.401A>C p.K134T | Missense Mutation (SNP) | VAF 29/53 reads (55%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.624); catalogued as COSV55802504; called by muse, mutect2, varscan2
- ERN2 | c.2741C>A p.S914* | Nonsense Mutation (SNP) | VAF 6/13 reads (46%) | catalogued as COSV99891950; called by muse, mutect2
- ERVW-1 | c.1270C>T p.R424* | Nonsense Mutation (SNP) | VAF 8/24 reads (33%) | catalogued as rs1038278481, COSV71259665; called by muse, mutect2, varscan2
- ESF1 | c.2169C>A p.F723L | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99176446; called by muse, mutect2, varscan2
- ESRRG | c.532A>G p.K178E | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100753486; called by muse, mutect2, varscan2
- EXOC4 | c.260G>A p.R87Q | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.973); catalogued as rs199786320, COSV54094022; called by muse, mutect2, varscan2
- EXOC6 | c.192G>T p.K64N | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); catalogued as COSV99592243; called by muse, mutect2, varscan2
- EXOG | c.548G>A p.R183Q | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1050050130, COSV99815395; called by muse, mutect2, varscan2
- EYA1 | c.880C>T p.R294* | Nonsense Mutation (SNP) | VAF 29/53 reads (55%) | catalogued as CM980645, COSV100378534, COSV100379912, COSV58162866; called by muse, mutect2, varscan2
- F11 | c.1393G>T p.E465* | Nonsense Mutation (SNP) | VAF 15/40 reads (38%) | catalogued as CM031977, COSV53001376; called by muse, mutect2, varscan2
- F13A1 | c.1666G>A p.A556T | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.583); catalogued as COSV99343552; called by muse, mutect2, varscan2
- F8 | c.5209C>A p.L1737I | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.203); catalogued as COSV100811688, COSV64271136, COSV64276619; called by muse, mutect2, varscan2
- FAM124B | c.487G>A p.E163K | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.439); catalogued as COSV66272530; called by muse, mutect2, varscan2
- FAM214A | c.716G>T p.R239I | Missense Mutation (SNP) | VAF 40/83 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.627); catalogued as rs1401482356, COSV99958244; called by muse, mutect2, varscan2
- FAM9C | c.288G>T p.K96N | Missense Mutation (SNP) | VAF 38/91 reads (42%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.728); catalogued as COSV100452848; called by muse, mutect2, varscan2
- FAT2 | c.478G>A p.D160N | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT tolerated (0.65); PolyPhen benign (0.291); catalogued as COSV99943654; called by muse, mutect2, varscan2
- FAT3 | c.162G>T p.E54D | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99965239; called by muse, mutect2, varscan2
- FAT3 | c.4636C>T p.R1546* | Nonsense Mutation (SNP) | VAF 9/27 reads (33%) | catalogued as rs866154457, COSV53094050; called by muse, mutect2, varscan2
- FBLN2 | c.2754G>T p.E918D | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99852265; called by muse, mutect2, varscan2
- FBXO22 | c.591G>T p.K197N | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.521); catalogued as COSV57617071; called by muse, mutect2, varscan2
- FBXO5 | c.1326G>T p.K442N | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.118); catalogued as COSV99999892; called by muse, mutect2, varscan2
- FCER1A | c.168C>A p.F56L | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV63666623, COSV63667526; called by muse, mutect2, varscan2
- FFAR2 | c.602G>A p.R201H | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.971); catalogued as rs780784883, COSV99876129; called by muse, mutect2, varscan2
- FGD6 | c.2914G>T p.E972* | Nonsense Mutation (SNP) | VAF 18/35 reads (51%) | catalogued as COSV59697534; called by muse, mutect2, varscan2
- FLT1 | c.2900C>T p.A967V | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated (0.39); PolyPhen benign (0.088); catalogued as rs371199947; called by muse, mutect2, varscan2
- FMN2 | c.4402C>T p.R1468C | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.588); catalogued as rs748812254, COSV100144530, COSV60425638; called by muse, mutect2, varscan2
- FMO2 | c.1159C>T p.R387C | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs1381884236, COSV52947425, COSV99269351; called by muse, mutect2, varscan2
- FNBP1 | c.151A>C p.K51Q | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100852751; called by muse, varscan2
- FNDC1 | c.448G>T p.E150* | Nonsense Mutation (SNP) | VAF 15/25 reads (60%) | catalogued as COSV51944157, COSV99796281; called by muse, mutect2, varscan2
- FOXM1 | c.1198C>T p.P400S | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.49); PolyPhen benign (0.107); catalogued as COSV100700882; called by muse, mutect2, varscan2
- FRMPD2 | c.2560G>T p.E854* | Nonsense Mutation (SNP) | VAF 9/28 reads (32%) | catalogued as COSV100564016, COSV59720132; called by muse, mutect2, varscan2
- FRMPD2 | c.1007A>C p.K336T | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100564020; called by muse, mutect2, varscan2
- FRMPD4 | c.739C>T p.L247F | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.748); catalogued as COSV101043578; called by muse, mutect2, varscan2
- FRMPD4 | c.977A>G p.K326R | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.867); catalogued as COSV101043579; called by muse, mutect2, varscan2
- FRYL | c.4979G>A p.R1660Q | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as rs771423782, COSV51943593, COSV99976742; called by muse, mutect2, varscan2
- FSIP1 | c.371A>C p.K124T | Missense Mutation (SNP) | VAF 38/105 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.107); catalogued as COSV100618210; called by muse, mutect2, varscan2
- GABRA2 | c.743G>T p.R248I | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100734590, COSV62911664; called by muse, mutect2, varscan2
- GABRA4 | c.847G>T p.E283* | Nonsense Mutation (SNP) | VAF 7/40 reads (18%) | catalogued as COSV51924068; called by muse, mutect2, varscan2
- GALNT13 | c.896G>T p.R299I | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.099); catalogued as COSV101223796, COSV67220220; called by muse, mutect2, varscan2
- GALNT15 | c.49C>T p.L17F | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.996); catalogued as COSV100327865; called by muse, mutect2, varscan2
- GALNT15 | c.1183G>A p.E395K | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs535247367, COSV60215618, COSV60219267; called by muse, mutect2, varscan2
- GALNT7 | c.818G>A p.R273Q | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs775788103, COSV53926777; called by muse, mutect2, varscan2
- GALNT8 | c.1360-1G>T p.X454_splice | Splice Site (SNP) | VAF 18/58 reads (31%) | catalogued as COSV52897392; called by muse, mutect2, varscan2
- GBP2 | c.1748C>A p.S583* | Nonsense Mutation (SNP) | VAF 30/70 reads (43%) | catalogued as COSV100975412; called by muse, varscan2
- GGPS1 | c.34C>A p.L12I | Missense Mutation (SNP) | VAF 28/54 reads (52%) | SIFT tolerated (0.26); PolyPhen benign (0.179); catalogued as COSV99270540; called by muse, mutect2, varscan2
- GIPC2 | c.747G>T p.K249N | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.399); catalogued as COSV100883297; called by muse, mutect2, varscan2
- GLB1L3 | c.884A>C p.K295T | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.463); catalogued as COSV101111102; called by muse, mutect2, varscan2
- GLO1 | c.177A>C p.Q59H | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.047); catalogued as COSV100974105; called by muse, mutect2, varscan2
- GLRA1 | c.408C>A p.F136L | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV51007438, COSV51008702; called by muse, mutect2, varscan2
- GLRA4 | c.1178C>A p.S393Y | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.057); catalogued as COSV100129065; called by muse, mutect2, varscan2
- GLYATL1 | c.475G>A p.D159N (on ENST00000317391 / NM_001354699.1; = p.D190N on NM_080661.4) | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.994); catalogued as COSV55612323; called by muse, mutect2, varscan2
- GP5 | c.1637T>G p.I546S | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.094); catalogued as COSV100540979; called by muse, mutect2, varscan2
- GPM6B | c.405G>A p.M135I | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.4); PolyPhen benign (0.173); catalogued as COSV100366391; called by muse, mutect2, varscan2
- GPR135 | c.1291C>T p.R431* | Nonsense Mutation (SNP) | VAF 22/38 reads (58%) | catalogued as rs546298096, COSV67749423; called by muse, mutect2, varscan2
- GPR139 | c.649C>T p.R217C | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as rs942765597, COSV58501549; called by muse, mutect2, varscan2
- GPR143 | c.359C>T p.A120V | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as rs751622915, COSV66632596; called by muse, mutect2, varscan2
- GPR161 | c.460C>A p.H154N | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.97); catalogued as COSV99606978; called by muse, mutect2, varscan2
- GPR174 | c.148G>T p.E50* | Nonsense Mutation (SNP) | VAF 25/51 reads (49%) | catalogued as COSV52132502, COSV99338385; called by muse, mutect2, varscan2
- GPR179 | c.3761C>T p.T1254M (on ENST00000621958; = p.T1253M on NM_001004334.4) | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.31); PolyPhen benign (0.039); catalogued as rs781377071; called by muse, mutect2, varscan2
- GRAMD1C | c.108G>T p.E36D | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.967); catalogued as COSV100822850, COSV63982318; called by muse, mutect2, varscan2
- GRHL3 | c.46G>A p.D16N (on ENST00000350501 / NM_198174.3; = p.D21N on NM_021180.3) | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs753938538, COSV52566959; called by muse, mutect2, varscan2
- GRIA1 | c.2484C>A p.F828L | Missense Mutation (SNP) | VAF 39/100 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.32); catalogued as COSV99601169; called by muse, mutect2, varscan2
- GRIA4 | c.2040C>A p.F680L | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs141120060, COSV99233276; called by muse, mutect2
- GRIP1 | c.499C>T p.R167* | Nonsense Mutation (SNP) | VAF 10/27 reads (37%) | catalogued as COSV54028453; called by muse, mutect2, varscan2
- GRM4 | c.136G>T p.D46Y | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV100946603; called by muse, mutect2, varscan2
- GRM6 | c.2560C>T p.R854* | Nonsense Mutation (SNP) | VAF 23/36 reads (64%) | catalogued as rs753571357, COSV51434064; called by muse, mutect2, varscan2
- GSR | c.463A>C p.N155H | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.996); catalogued as COSV99645703; called by mutect2, varscan2
- GUCY2C | c.1365-1G>T p.X455_splice | Splice Site (SNP) | VAF 8/34 reads (24%) | catalogued as COSV53790603, COSV99663918; called by muse, mutect2, varscan2
- GUCY2D | c.1618C>T p.R540C | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.013); catalogued as rs61749754, CM002037; ClinVar: not provided; called by muse, mutect2, varscan2
- HBP1 | c.1123C>T p.R375C | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99753021; called by muse, mutect2, varscan2
- HCFC1 | c.334G>A p.E112K | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV60070110; called by muse, mutect2, varscan2
- HCN1 | c.2144G>A p.R715Q | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.992); catalogued as rs1242068538, COSV100302034, COSV57497988; called by muse, mutect2, varscan2
- HDX | c.1771G>T p.D591Y | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1288774304, COSV99947713; called by muse, mutect2, varscan2
- HECTD4 | c.5300C>T p.A1767V | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.46); catalogued as COSV101108074; called by muse, mutect2, varscan2
- HECTD4 | c.4348G>T p.E1450* | Nonsense Mutation (SNP) | VAF 9/21 reads (43%) | catalogued as COSV100296145; called by muse, mutect2, varscan2
- HEPH | c.1734C>A p.F578L (on ENST00000343002; = p.F311L on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.355); catalogued as rs373849962, COSV57961457, COSV57970622; called by muse, mutect2, varscan2
- HEPHL1 | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.119); catalogued as COSV100244132; called by muse, mutect2, varscan2
- HERC1 | c.2567C>T p.P856L | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.996); catalogued as COSV101496738; called by muse, mutect2, varscan2
- HHIP | c.1024T>G p.F342V | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT tolerated (0.05); PolyPhen benign (0.276); catalogued as rs1560713883, COSV99667569; called by muse, mutect2, varscan2
- HIPK1 | c.2726G>A p.R909Q | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated (0.14); PolyPhen benign (0.099); catalogued as rs370415621, COSV61245810; called by muse, mutect2, varscan2
- HKDC1 | c.1678G>A p.A560T | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.017); catalogued as rs150227380, COSV63575340; called by muse, mutect2, varscan2
- HMCN1 | c.9068T>G p.I3023S | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.84); PolyPhen probably damaging (0.99); catalogued as COSV99632629; called by muse, mutect2, varscan2
- HMCN1 | c.9989G>A p.R3330Q | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.993); catalogued as rs780529619, COSV54878805; called by muse, mutect2, varscan2
- HMGXB4 | c.422C>T p.S141L | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT tolerated, low confidence (0.16); PolyPhen possibly damaging (0.672); catalogued as rs199695099, COSV53333300; called by muse, mutect2, varscan2
- HOXA11 | c.907C>A p.R303S | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV99136055; called by muse, varscan2
- HOXA11 | c.805G>T p.E269* | Nonsense Mutation (SNP) | VAF 10/40 reads (25%) | catalogued as COSV99136057; called by muse, varscan2
- HOXA2 | c.515G>A p.R172Q | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99761322; called by muse, mutect2, varscan2
- HPS3 | c.2996G>A p.R999Q | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT tolerated (0.93); PolyPhen benign (0.003); catalogued as rs527240120, COSV52834020; called by muse, mutect2, varscan2
- HSPA4 | c.183G>T p.K61N | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.583); catalogued as COSV100507765; called by muse, mutect2, varscan2
- HUWE1 | c.8109G>T p.K2703N | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.95); catalogued as COSV53364255; called by muse, mutect2, varscan2
- IFI44L | c.661T>G p.F221V | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100655046; called by muse, mutect2, varscan2
- IFT52 | c.97C>T p.R33W | Missense Mutation (SNP) | VAF 25/44 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs547710015, COSV100887643; called by muse, mutect2
- IGSF9B | c.2034G>A p.Q678= | Splice Region (SNP) | VAF 7/17 reads (41%) | catalogued as COSV100318073; called by muse, mutect2, varscan2
- IL15 | c.61C>A p.L21I | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV99650708; called by muse, mutect2, varscan2
- IL1RAPL1 | c.1027C>T p.R343* | Nonsense Mutation (SNP) | VAF 15/46 reads (33%) | catalogued as rs1475549924, COSV56258619; called by muse, mutect2, varscan2
- IL22RA1 | c.553G>T p.E185* | Nonsense Mutation (SNP) | VAF 8/21 reads (38%) | catalogued as COSV99583180; called by muse, mutect2, varscan2
- ILF3 | c.230C>T p.A77V | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.013); catalogued as rs540302759, COSV99139989; called by muse, mutect2, varscan2
- INSYN2A | c.38C>T p.T13M | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV54765595; called by muse, mutect2, varscan2
- INTS7 | c.1615C>A p.H539N | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV100877542; called by muse, mutect2, varscan2
- INTS8 | c.1928G>A p.R643Q | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.737); catalogued as rs1356821906, COSV100569365; called by muse, mutect2, varscan2
- IQGAP3 | c.4601C>A p.S1534Y | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV100752234; called by muse, varscan2
- IQSEC2 | c.883C>T p.R295W (on ENST00000642864 / NM_001111125.3; = p.R90W on NM_015075.2) | Missense Mutation (SNP) | VAF 17/28 reads (61%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV64728188; called by muse, mutect2, varscan2
- IQSEC3 | c.2559G>T p.E853D (on ENST00000538872 / NM_001170738.2; = p.E550D on NM_015232.1) | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.118); catalogued as COSV100407431; called by muse, mutect2, varscan2
- ITGA1 | c.1681G>T p.E561* | Nonsense Mutation (SNP) | VAF 4/16 reads (25%) | catalogued as COSV99251771; called by muse, mutect2
- ITGA4 | c.1807C>A p.L603I | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52001410, COSV52002465, COSV52003753; called by muse, mutect2, varscan2
- ITGAD | c.2096G>A p.R699Q | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.38); PolyPhen benign (0.089); catalogued as rs749195220, COSV66758030; called by muse, mutect2, varscan2
- ITGAV | c.1704G>T p.L568F | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT tolerated (0.77); PolyPhen probably damaging (0.989); catalogued as COSV99655362; called by muse, mutect2, varscan2
- ITGB1BP1 | c.146G>T p.S49I | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99432102; called by muse, mutect2, varscan2
- ITGBL1 | c.644A>C p.K215T | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV101095559; called by muse, mutect2, varscan2
- ITM2A | c.399C>A p.F133L | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs758783754, COSV64811768; called by muse, mutect2, varscan2
- ITPRID1 | c.178G>T p.E60* | Nonsense Mutation (SNP) | VAF 14/33 reads (42%) | catalogued as COSV100087030, COSV60073986; called by muse, mutect2, varscan2
- ITSN2 | c.1671G>T p.E557D | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.97); catalogued as COSV100743915; called by muse, mutect2, varscan2
- JMY | c.1312G>T p.D438Y | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101268077; called by muse, mutect2, varscan2
- JUP | c.256C>T p.R86W | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs782240305, COSV100159694; called by muse, mutect2, varscan2
- KASH5 | c.89T>C p.V30A | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.037); catalogued as COSV101483478; called by muse, mutect2, varscan2
- KCNG1 | c.293T>C p.F98S | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0.326); catalogued as COSV100857137; called by muse, mutect2, varscan2
- KCNH4 | c.934G>A p.D312N | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52917086; called by muse, mutect2, varscan2
- KCNIP3 | c.217C>T p.R73C | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.27); PolyPhen benign (0.049); catalogued as rs199540663, COSV99734235; called by muse, mutect2, varscan2
- KCNQ3 | c.1525G>A p.E509K | Missense Mutation (SNP) | VAF 41/101 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as rs774311301, COSV66468995; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KCNQ3 | c.452T>G p.V151G | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT tolerated (0.52); PolyPhen benign (0.057); catalogued as COSV101196277; called by muse, mutect2, varscan2
- KCNT2 | c.1677G>T p.E559D | Missense Mutation (SNP) | VAF 30/59 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs751143025, COSV54064425, COSV54072967; called by muse, mutect2, varscan2
- KDM4A | c.283C>T p.R95* | Nonsense Mutation (SNP) | VAF 10/34 reads (29%) | catalogued as COSV64959510; called by muse, mutect2, varscan2
- KEAP1 | c.1497G>T p.M499I | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT tolerated (0.41); PolyPhen benign (0.035); catalogued as COSV99408050; called by muse, mutect2
- KHDC3L | c.509C>A p.S170Y | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV100950424, COSV64864085; called by muse, mutect2, varscan2
- KIAA1109 | c.1255G>T p.E419* | Nonsense Mutation (SNP) | VAF 24/90 reads (27%) | catalogued as COSV99167872; called by muse, mutect2, varscan2
- KIAA1109 | c.14810C>A p.S4937Y | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52661999; called by muse, mutect2, varscan2
- KIAA1210 | c.4248A>C p.K1416N | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.35); catalogued as COSV101274315; called by muse, mutect2, varscan2
- KIAA1210 | c.835T>G p.S279A | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.67); PolyPhen possibly damaging (0.681); catalogued as COSV101274317; called by muse, mutect2, varscan2
- KIF15 | c.2631G>T p.E877D | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT tolerated (0.08); PolyPhen benign (0.14); catalogued as COSV100393040; called by muse, mutect2, varscan2
- KIF16B | c.2552A>C p.K851T | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.013); catalogued as COSV100734696; called by muse, mutect2, varscan2
- KIF17 | c.590C>T p.S197L | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.589); catalogued as rs762645455, COSV56122474; called by muse, mutect2, varscan2
- KIF27 | c.2224G>T p.E742* | Nonsense Mutation (SNP) | VAF 29/62 reads (47%) | catalogued as COSV52831679, COSV52832338; called by muse, mutect2, varscan2
- KIF2B | c.1667C>T p.P556L | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs543418582, COSV99275073; called by muse, varscan2
- KIF5B | c.1426C>T p.R476C | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs774369338, COSV100192156; called by mutect2, varscan2
- KIF5C | c.648G>T p.E216D | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.811); catalogued as COSV101276173; called by muse, mutect2, varscan2
- KLHL38 | c.1499A>C p.K500T | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT tolerated (0.05); PolyPhen benign (0.074); catalogued as COSV100384494; called by muse, mutect2, varscan2
- KLRD1 | c.38C>A p.S13Y | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60274298, COSV60274350; called by muse, mutect2, varscan2
- KNG1 | c.627G>T p.E209D | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT tolerated (0.17); PolyPhen benign (0.137); catalogued as COSV53976394, COSV53977988; called by muse, mutect2, varscan2
- KNTC1 | c.3554A>C p.K1185T | Missense Mutation (SNP) | VAF 33/65 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as COSV100338561; called by muse, mutect2, varscan2
- KRBOX4 | c.413C>A p.S138Y (on ENST00000344302 / NM_001129898.2; = p.S133Y on NM_017776.2) | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.979); catalogued as COSV53343148; called by muse, mutect2, varscan2
- KRR1 | c.831+2T>C p.X277_splice | Splice Site (SNP) | VAF 48/129 reads (37%) | catalogued as COSV99875785; called by muse, mutect2, varscan2
- KRTAP13-2 | c.296C>A p.S99Y | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.199); catalogued as COSV67761943, COSV67762090; called by muse, mutect2, varscan2
- KRTAP6-1 | c.15C>A p.Y5* | Nonsense Mutation (SNP) | VAF 64/145 reads (44%) | catalogued as COSV100228808; called by muse, mutect2, varscan2
- LAIR1 | c.62C>T p.T21M | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.024); catalogued as rs746673117, COSV57308701; called by muse, mutect2, varscan2
- LAMA1 | c.5009-1G>T p.X1670_splice | Splice Site (SNP) | VAF 22/38 reads (58%) | catalogued as COSV67531882; called by muse, mutect2, varscan2
- LCE3E | c.175C>T p.R59C | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.312); catalogued as rs199901484; called by muse, mutect2, varscan2
- LEMD3 | c.2422G>T p.E808* | Nonsense Mutation (SNP) | VAF 14/36 reads (39%) | catalogued as COSV100384478; called by muse, mutect2, varscan2
- LETMD1 | c.162G>T p.K54N | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.795); catalogued as COSV100016463; called by muse, mutect2, varscan2
- LINGO2 | c.649C>T p.P217S | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.5); PolyPhen benign (0.206); catalogued as COSV100430895; called by muse, mutect2, varscan2
- LMOD2 | c.1496C>A p.S499Y | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as rs375211570; called by muse, mutect2, varscan2
- LONRF3 | c.1174A>C p.K392Q (on ENST00000371628 / NM_001031855.3; = p.K351Q on NM_024778.5) | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as COSV100504538; called by muse, mutect2, varscan2
- LRCH2 | c.643C>A p.Q215K | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.973); catalogued as COSV100407219; called by muse, mutect2, varscan2
- LRRC23 | c.688C>T p.R230* | Nonsense Mutation (SNP) | VAF 15/34 reads (44%) | catalogued as rs782412116, COSV50397652; called by muse, mutect2, varscan2
- LRRC39 | c.344G>A p.R115Q | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs1020021088, COSV61582596; called by muse, mutect2
- LRRC4 | c.1624G>A p.A542T | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.145); catalogued as rs1386554042, COSV50813364; called by muse, mutect2, varscan2
- LUZP4 | c.796C>A p.L266I | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.093); catalogued as COSV100904864; called by muse, mutect2, varscan2
- MAGEC3 | c.333G>T p.K111N | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.044); catalogued as COSV100025811; called by muse, mutect2, varscan2
- MAGI2 | c.3050C>T p.S1017L | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.979); catalogued as rs961359642, COSV100835513; called by muse, mutect2, varscan2
- MAOA | c.992C>T p.A331V | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.577); catalogued as COSV100108903; called by muse, mutect2, varscan2
- MAP3K1 | c.1091G>A p.R364Q | Missense Mutation (SNP) | VAF 42/78 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV68124965; called by muse, mutect2, varscan2
- MAP3K1 | c.4027G>T p.E1343* | Nonsense Mutation (SNP) | VAF 19/54 reads (35%) | catalogued as COSV68122689, COSV68127321; called by muse, varscan2
- MAP3K8 | c.488G>T p.R163I | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.996); catalogued as COSV99552250; called by muse, mutect2, varscan2
- MAP7D3 | c.698C>T p.S233L | Missense Mutation (SNP) | VAF 43/99 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.31); catalogued as COSV60171013; called by muse, mutect2, varscan2
- MATN1 | c.1201G>T p.D401Y | Missense Mutation (SNP) | VAF 17/30 reads (57%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as COSV101056245, COSV65650906; called by muse, mutect2, varscan2
- MB21D2 | c.124G>T p.E42* | Nonsense Mutation (SNP) | VAF 7/16 reads (44%) | catalogued as COSV101165138; called by muse, mutect2, varscan2
- MCHR2 | c.982G>T p.E328* | Nonsense Mutation (SNP) | VAF 17/34 reads (50%) | catalogued as COSV56000050, COSV56003328; called by muse, mutect2, varscan2
- MDC1 | c.5479C>T p.P1827S | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT tolerated (0.53); PolyPhen benign (0.196); catalogued as COSV100902983, COSV64525064; called by muse, mutect2
- MDC1 | c.3692G>T p.R1231I | Missense Mutation (SNP) | VAF 39/108 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.588); catalogued as rs771197050, COSV100902984; called by muse, mutect2, varscan2
- MEAF6 | c.239G>A p.R80Q | Missense Mutation (SNP) | VAF 14/22 reads (64%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.867); catalogued as COSV56162605, COSV56163847; called by muse, mutect2, varscan2
- MECOM | c.301G>A p.E101K | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs758678191, COSV72110712; called by muse, mutect2, varscan2
- MED12 | c.1779C>A p.F593L | Missense Mutation (SNP) | VAF 23/43 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100379082; called by muse, mutect2, varscan2
- MED12L | c.1990G>T p.E664* | Nonsense Mutation (SNP) | VAF 9/47 reads (19%) | catalogued as COSV99853979; called by muse, mutect2, varscan2
- MEF2C | c.1001C>A p.S334Y | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.794); catalogued as COSV100425805; called by muse, mutect2, varscan2
- MEPE | c.479C>T p.A160V | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs753432480, COSV63072852; called by muse, varscan2
- MIGA1 | c.399G>T p.Q133H | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); catalogued as COSV100889792; called by muse, mutect2, varscan2
- MINK1 | c.1793G>A p.R598Q | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.885); catalogued as rs1166428542, COSV61789366; called by muse, mutect2, varscan2
- MLH1 | c.2049C>A p.F683L | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.709); catalogued as COSV99212551; called by muse, mutect2, varscan2
- MMRN1 | c.221C>A p.S74Y | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated, low confidence (0.29); PolyPhen possibly damaging (0.641); catalogued as COSV53342036, COSV99307457; called by muse, mutect2, varscan2
- MMRN1 | c.2776G>A p.E926K | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.735); catalogued as rs762148913, COSV53333574; called by muse, mutect2, varscan2
- MNX1 | c.18T>G p.N6K | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99429737; called by muse, mutect2, varscan2
- MOGAT2 | c.706C>T p.P236S | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.67); PolyPhen benign (0.026); catalogued as COSV52219731; called by muse, mutect2, varscan2
- MOV10L1 | c.3320C>T p.S1107L | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53167559; called by muse, mutect2, varscan2
- MROH5 | c.3412C>T p.R1138W | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372564585; called by muse, mutect2, varscan2
- MRPL3 | c.937A>T p.N313Y | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as COSV99394935; called by muse, mutect2, varscan2
- MSN | c.1431G>T p.E477D | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.43); PolyPhen benign (0.216); catalogued as COSV100814262; called by muse, mutect2, varscan2
- MTMR10 | c.124G>T p.E42* | Nonsense Mutation (SNP) | VAF 19/42 reads (45%) | catalogued as COSV58727710; called by muse, mutect2, varscan2
- MTRF1L | c.719G>T p.R240I | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100922457; called by muse, mutect2, varscan2
- MUC17 | c.11153C>A p.S3718Y | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV60304852; called by muse, mutect2, varscan2
- MYBPC2 | c.2674G>A p.D892N | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV100731930; called by muse, mutect2, varscan2
- MYH14 | c.5194G>A p.D1732N | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.689); catalogued as COSV99223494; called by muse, mutect2, varscan2
- MYH15 | c.907C>A p.L303I | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.85); catalogued as COSV56304748; called by muse, mutect2, varscan2
- MYLK3 | c.2001G>T p.E667D | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.369); catalogued as COSV101189156; called by muse, mutect2, varscan2
- MYO1H | c.2080C>T p.R694C | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764150151, COSV60443340; called by muse, mutect2, varscan2
- MYO7A | c.3242A>C p.K1081T | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.461); catalogued as COSV68684614; called by muse, mutect2, varscan2
- MYOCD | c.979A>C p.N327H | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.429); catalogued as COSV100591095; called by muse, mutect2, varscan2
- NAV3 | c.3467G>A p.R1156K | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV57081684; called by muse, mutect2, varscan2
- NBAS | c.2251G>A p.D751N | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.435); catalogued as rs577208192, COSV55737765; called by muse, mutect2, varscan2
- NCAPG | c.1373G>A p.R458K | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV52268405, COSV99266091; called by muse, mutect2, varscan2
- NCKIPSD | c.1196G>A p.R399H | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.64); catalogued as COSV99584089; called by muse, mutect2, varscan2
- NCOA4 | c.137G>A p.R46Q | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.324); catalogued as rs1554923257; called by muse, mutect2, varscan2
- NDST3 | c.679C>A p.H227N | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious (0.02); PolyPhen benign (0.311); catalogued as COSV56632147, COSV99631255; called by muse, mutect2, varscan2
- NEDD1 | c.194A>C p.K65T | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV57145113, COSV99901178; called by muse, mutect2, varscan2
- NEDD4L | c.1786G>T p.E596* (on ENST00000400345 / NM_001144967.3; = p.E576* on NM_015277.6) | Nonsense Mutation (SNP) | VAF 6/20 reads (30%) | catalogued as COSV99895871; called by muse, mutect2, varscan2
- NEFL | c.1357G>A p.E453K | Missense Mutation (SNP) | VAF 53/111 reads (48%) | SIFT tolerated (0.13); PolyPhen benign (0.238); catalogued as rs1249514180, COSV99647917; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NF1 | c.5594C>A p.S1865Y (on ENST00000358273 / NM_001042492.3; = p.S1844Y on NM_000267.3) | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV100647755; called by muse, mutect2, varscan2
- NFE2L2 | c.1687G>A p.E563K | Missense Mutation (SNP) | VAF 41/80 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); catalogued as rs763240080, COSV67960917; called by muse, mutect2, varscan2
- NFKBIZ | c.505G>A p.D169N | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.51); catalogued as rs746465069, COSV100397143; called by muse, mutect2, varscan2
- NHS | c.2635C>T p.R879* | Nonsense Mutation (SNP) | VAF 7/19 reads (37%) | catalogued as CM064154, COSV101196371; called by muse, mutect2, varscan2
- NIBAN1 | c.413G>A p.R138K | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT tolerated (0.94); PolyPhen benign (0.003); catalogued as COSV100836486; called by muse, mutect2, varscan2
- NLRC3 | c.3097C>T p.Q1033* | Nonsense Mutation (SNP) | VAF 7/20 reads (35%) | catalogued as rs996780399, COSV100073077; called by muse, mutect2, varscan2
- NLRP1 | c.2284C>T p.R762C | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs146908613; called by muse, mutect2, varscan2
- NOBOX | c.1352C>T p.A451V | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT tolerated (0.14); PolyPhen benign (0.071); catalogued as COSV99779579; called by muse, varscan2
- NOL11 | c.2086C>T p.R696W | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.732); catalogued as rs748697836, COSV99475199; called by muse, mutect2, varscan2
- NONO | c.250G>A p.D84N | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.809); catalogued as COSV99339017; called by muse, mutect2, varscan2
- NOS2 | c.1717G>A p.D573N | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.076); catalogued as COSV100569788; called by muse, mutect2, varscan2
- NPEPPS | c.2215C>A p.L739I | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.268); catalogued as rs1395763439, COSV100443491, COSV59104129; called by muse, mutect2, varscan2
- NR1H4 | c.560G>T p.R187I (on ENST00000551379 / NM_001206993.2; = p.R177I on NM_005123.4) | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51851221, COSV51856875; called by muse, mutect2, varscan2
- NRDC | c.331A>G p.K111E | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.899); catalogued as COSV100703619; called by muse, mutect2, varscan2
- NRK | c.2480C>T p.S827L | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs760939013, COSV54589912; called by muse, mutect2, varscan2
- NSUN2 | c.397C>T p.R133* | Nonsense Mutation (SNP) | VAF 9/22 reads (41%) | catalogued as rs1333817754, COSV52955809, COSV52957008, COSV99243249; called by muse, mutect2, varscan2
- NSUN6 | c.232-1G>A p.X78_splice | Splice Site (SNP) | VAF 10/32 reads (31%) | catalogued as rs765997175, COSV101045803; called by muse, mutect2
- NSUN7 | c.203T>C p.I68T | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.218); catalogued as COSV100349475; called by mutect2, varscan2
- NTRK2 | c.2026G>A p.D676N (on ENST00000323115 / NM_001369534.1; = p.D692N on NM_006180.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52871416; called by muse, mutect2, varscan2
- NTS | c.494G>A p.R165K | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55456050, COSV99755095; called by muse, mutect2, varscan2
- NUP205 | c.5657G>A p.R1886Q | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.381); catalogued as rs868238259, COSV99607303; called by muse, mutect2, varscan2
- NXF3 | c.241C>T p.R81C | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as rs764300277, COSV67702597; called by muse, mutect2, varscan2
- OCIAD1 | c.497C>A p.S166Y | Missense Mutation (SNP) | VAF 16/25 reads (64%) | SIFT tolerated (0.06); PolyPhen benign (0.224); catalogued as rs144566344; called by muse, mutect2, varscan2
- OCRL | c.1676A>C p.N559T | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100843506; called by muse, mutect2, varscan2
- OR13C3 | c.727G>A p.V243I | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.029); catalogued as COSV101053339; called by muse, mutect2, varscan2
- OR13F1 | c.716C>A p.S239* | Nonsense Mutation (SNP) | VAF 7/40 reads (18%) | catalogued as COSV58252549; called by muse, mutect2, varscan2
- OR13H1 | c.208G>A p.D70N | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100088337; called by muse, mutect2, varscan2
- OR1I1 | c.443C>A p.S148* | Nonsense Mutation (SNP) | VAF 13/21 reads (62%) | catalogued as COSV99264873; called by muse, mutect2, varscan2
- OR2D3 | c.8C>T p.S3F | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs868122480, COSV100505114; called by muse, mutect2, varscan2
- OR2L2 | c.828C>A p.F276L | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.232); catalogued as COSV100824126; called by muse, mutect2, varscan2
- OR2W1 | c.355T>C p.S119P | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs776090951, COSV101013927; called by muse, mutect2
- OR51B4 | c.904C>T p.R302C | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as rs754916789, COSV66517085, COSV66517243; called by muse, mutect2, varscan2
- OR56A4 | c.1084C>A p.L362M | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.477); catalogued as COSV100417635; called by muse, mutect2, varscan2
- OR6X1 | c.368C>T p.T123I | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV100020606; called by muse, mutect2, varscan2
- OR7C2 | c.240G>T p.K80N | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.938); catalogued as COSV99934590; called by muse, mutect2, varscan2
- OR7D2 | c.659G>A p.R220Q | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0.001); catalogued as rs753509176, COSV60138781; called by muse, mutect2, varscan2
- ORC2 | c.1454C>T p.T485I | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs150650400, COSV99309649; called by muse, mutect2, varscan2
- ORC4 | c.865C>T p.R289* | Nonsense Mutation (SNP) | VAF 19/31 reads (61%) | catalogued as rs1267664245, COSV99932381; called by muse, mutect2, varscan2
- P2RY13 | c.907C>A p.L303I | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56378025; called by muse, mutect2, varscan2
- PAH | c.157C>T p.R53C | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.02); catalogued as rs199475619, CM010948, COSV61017017; ClinVar: uncertain significance / not provided; called by muse, mutect2, varscan2
- PAK1IP1 | c.637C>A p.L213I | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT tolerated (0.39); PolyPhen benign (0.02); catalogued as rs1456355850, COSV65435203; called by muse, mutect2, varscan2
- PANK3 | c.140G>T p.S47I | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT deleterious (0.03); PolyPhen benign (0.278); catalogued as COSV53322937, COSV99496505; called by muse, mutect2, varscan2
- PAPOLB | c.1199G>A p.R400Q | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.693); catalogued as COSV68201845; called by muse, mutect2, varscan2
- PAPPA | c.2361C>A p.F787L | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as COSV100074772, COSV60283076; called by muse, mutect2, varscan2
- PAQR7 | c.176G>A p.R59H | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.432); catalogued as rs950403491, COSV100961592, COSV65351592; called by muse, mutect2, varscan2
- PAX6 | c.635G>T p.R212I | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99570661; called by muse, mutect2, varscan2
- PCDH11X | c.1249C>A p.L417I | Missense Mutation (SNP) | VAF 23/42 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53489302; called by muse, mutect2, varscan2
- PCDH15 | c.3799C>A p.L1267I | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.692); catalogued as rs1236577105, COSV100224475; called by muse, mutect2, varscan2
- PCDH15 | c.2716C>T p.P906S | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1179535423, COSV100224481; called by muse, mutect2, varscan2
- PCDH19 | c.1588G>A p.E530K | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.864); catalogued as COSV55260505; called by muse, mutect2, varscan2
- PCDH9 | c.2942C>A p.S981Y | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100122265; called by muse, mutect2
- PCDH9 | c.1048G>A p.D350N | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100122267; called by muse, mutect2, varscan2
- PCDHA5 | c.1703G>A p.R568Q | Missense Mutation (SNP) | VAF 43/110 reads (39%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.003); catalogued as rs781868655, COSV65353051; called by muse, mutect2, varscan2
- PCDHA7 | c.1952T>C p.V651A | Missense Mutation (SNP) | VAF 16/19 reads (84%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.679); catalogued as COSV100970871; called by muse, mutect2, varscan2
- PCDHB11 | c.2368C>T p.R790* | Nonsense Mutation (SNP) | VAF 13/32 reads (41%) | catalogued as rs1554285839, COSV61311264; called by muse, mutect2, varscan2
- PCDHB3 | c.932C>T p.A311V | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.007); catalogued as COSV50581438; called by mutect2, varscan2
- PCDHGA3 | c.1093G>T p.E365* | Nonsense Mutation (SNP) | VAF 4/14 reads (29%) | catalogued as COSV53983304, COSV99549007; called by muse, mutect2, varscan2
- PCDHGA3 | c.1249G>T p.E417* | Nonsense Mutation (SNP) | VAF 4/9 reads (44%) | catalogued as COSV99542647; called by muse, mutect2
- PCDHGB6 | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53922767; called by muse, mutect2, varscan2
- PCLO | c.15145T>G p.L5049V | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100434877, COSV61665816; called by muse, mutect2, varscan2
- PCLO | c.2700G>T p.E900D | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.065); catalogued as COSV100434880; called by muse, mutect2, varscan2
- PCM1 | c.1513G>T p.E505* | Nonsense Mutation (SNP) | VAF 9/20 reads (45%) | catalogued as COSV61514524; called by muse, mutect2, varscan2
- PCMTD2 | c.913C>T p.P305S | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV99829537; called by muse, mutect2, varscan2
- PCNX1 | c.5498C>A p.S1833Y | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV53101298; called by muse, mutect2, varscan2
- PCNX4 | c.3194C>T p.S1065F (on ENST00000406854 / NM_001330177.2; = p.S831F on NM_022495.5) | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV100470584; called by muse, mutect2, varscan2
- PDS5B | c.2500C>T p.R834* | Nonsense Mutation (SNP) | VAF 33/62 reads (53%) | catalogued as COSV59723647; called by muse, mutect2, varscan2
- PDZD2 | c.2419C>T p.R807C | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs752110304, COSV99225611; called by muse, mutect2, varscan2
- PDZD3 | c.622G>T p.D208Y (on ENST00000531114; = p.D142Y on NM_024791.4) | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.308); catalogued as COSV99424593; called by muse, mutect2, varscan2
- PENK | c.779G>T p.R260I | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100152411, COSV59243276; called by muse, mutect2
- PI4KA | c.2245G>A p.E749K | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.711); catalogued as rs1473722732, COSV55413265; called by muse, mutect2, varscan2
- PICALM | c.114G>T p.K38N | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV100708043; called by muse, mutect2, varscan2
- PIGF | c.158C>T p.A53V | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.45); PolyPhen benign (0.007); catalogued as rs753432355, COSV99482794; called by muse, mutect2, varscan2
- PIK3CG | c.2341G>A p.E781K | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs146675267, COSV63246846; called by muse, mutect2, varscan2
- PITPNM1 | c.1050C>A p.F350L | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as rs775010489, COSV62707660; called by muse, mutect2, varscan2
- PITPNM1 | c.315G>T p.E105D | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV56873687; called by muse, mutect2, varscan2
- PIWIL1 | c.824G>A p.R275Q | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs771090876, COSV55344694; called by muse, mutect2, varscan2
- PIWIL3 | c.2228C>T p.S743L | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as rs757818276, COSV100177818; called by muse, varscan2
- PKIA | c.172C>T p.R58* | Nonsense Mutation (SNP) | VAF 22/42 reads (52%) | catalogued as COSV100775105; called by muse, mutect2, varscan2
- PKP4 | c.1400G>T p.R467I | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101081284, COSV67677724; called by muse, mutect2, varscan2
- PLA1A | c.176C>T p.S59L | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as rs761764931, COSV56330431; called by muse, varscan2
- PLA2G4C | c.68G>A p.R23Q | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs377414088; called by muse, mutect2, varscan2
- PLEK | c.424G>T p.E142* | Nonsense Mutation (SNP) | VAF 13/22 reads (59%) | catalogued as rs1432060545, COSV52252449, COSV99311115; called by muse, mutect2, varscan2
- PLEKHM1 | c.2549T>C p.F850S | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as COSV101378816; called by muse, mutect2, varscan2
- PNO1 | c.251G>T p.R84I | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54560695; called by muse, mutect2, varscan2
- POF1B | c.1120G>A p.E374K | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs146172066, COSV99427068; called by muse, mutect2, varscan2
- POFUT2 | c.884G>T p.R295I | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100499346; called by muse, mutect2, varscan2
- POLQ | c.5502A>C p.Q1834H | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.417); catalogued as COSV99952583; called by muse, mutect2, varscan2
- POLR1C | c.856G>T p.E286* | Nonsense Mutation (SNP) | VAF 19/44 reads (43%) | catalogued as COSV99541197; called by muse, mutect2, varscan2
- POLR2F | c.298C>T p.R100C | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as rs753314655, COSV100329819; called by muse, varscan2
- PORCN | c.1157C>T p.S386L (on ENST00000326194 / NM_203475.3; = p.S375L on NM_022825.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.022); catalogued as rs900532510, COSV100400492; called by muse, mutect2, varscan2
- PPFIBP1 | c.1192G>A p.E398K (on ENST00000318304 / NM_177444.3; = p.E381K on NM_003622.4) | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.29); PolyPhen benign (0.306); catalogued as rs768895000, COSV99945171; called by muse, mutect2, varscan2
- PPP1R12B | c.926G>A p.R309Q | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.316); catalogued as rs368051793; called by muse, mutect2, varscan2
- PPP1R3A | c.2750C>A p.S917Y | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.3); PolyPhen benign (0.021); catalogued as COSV99493556; called by muse, mutect2, varscan2
- PREPL | c.224T>C p.L75P | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.091); catalogued as COSV99576334; called by muse, mutect2, varscan2
- PRKDC | c.9590T>G p.L3197R | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.438); catalogued as COSV100041761; called by muse, mutect2, varscan2
- PRKG2 | c.1302G>T p.M434I | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV100020215, COSV52331647; called by muse, mutect2, varscan2
- PRKG2 | c.454G>T p.D152Y | Missense Mutation (SNP) | VAF 17/28 reads (61%) | SIFT deleterious (0); PolyPhen benign (0.379); catalogued as COSV52328957; called by muse, mutect2, varscan2
- PRR15L | c.82G>A p.D28N | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT tolerated (0.28); PolyPhen benign (0.3); catalogued as COSV99846540; called by muse, mutect2, varscan2
- PRSS23 | c.571C>T p.R191* | Nonsense Mutation (SNP) | VAF 10/11 reads (91%) | catalogued as COSV54706309, COSV99722428; called by muse, mutect2, varscan2
- PRSS55 | c.12C>A p.F4L | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100153846; called by muse, mutect2, varscan2
- PRTG | c.2386C>T p.R796* | Nonsense Mutation (SNP) | VAF 14/40 reads (35%) | catalogued as rs1044612039, COSV66837362; called by muse, mutect2, varscan2
- PRUNE2 | c.8453C>T p.S2818F | Missense Mutation (SNP) | VAF 24/42 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56313926, COSV99796206; called by muse, mutect2, varscan2
- PRUNE2 | c.41G>A p.R14Q | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs745663522, COSV65027512; called by muse, mutect2, varscan2
- PSMD14 | c.517G>T p.E173* | Nonsense Mutation (SNP) | VAF 21/41 reads (51%) | catalogued as COSV101293945; called by muse, mutect2, varscan2
- PTEN | c.421C>A p.H141N | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100910589, COSV64292503; called by muse, mutect2, varscan2
- PTPN13 | c.2767C>T p.R923* | Nonsense Mutation (SNP) | VAF 9/20 reads (45%) | catalogued as COSV100364078; called by muse, mutect2, varscan2
- PTPRD | c.3157C>A p.L1053I | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as COSV61957219, COSV61980299, COSV61985452; called by muse, mutect2, varscan2
- PTPRZ1 | c.1467C>A p.F489L | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV101100528, COSV66432313; called by muse, mutect2, varscan2
- PXDN | c.1892C>T p.A631V | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748463199, COSV99414278; called by muse, mutect2, varscan2
- PYROXD2 | c.340C>T p.R114* | Nonsense Mutation (SNP) | VAF 6/14 reads (43%) | catalogued as rs757147452, COSV65328998; called by muse, mutect2, varscan2
- QSER1 | c.4526C>A p.S1509* (on ENST00000399302; = p.S1638* on NM_001076786.3) | Nonsense Mutation (SNP) | VAF 4/16 reads (25%) | catalogued as COSV101234928; called by muse, varscan2
- RAB3GAP1 | c.180G>T p.E60D | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT tolerated (0.18); PolyPhen benign (0.034); catalogued as COSV99921474; called by muse, mutect2, varscan2
- RAB3GAP1 | c.2395G>A p.E799K | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT tolerated (0.06); PolyPhen benign (0.401); catalogued as rs781001414, COSV51483373; called by muse, mutect2, varscan2
- RAD9B | c.1249G>T p.E417* | Nonsense Mutation (SNP) | VAF 13/51 reads (25%) | catalogued as rs762718499, COSV62826072; called by muse, mutect2, varscan2
- RADX | c.1882C>A p.L628I | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.36); PolyPhen benign (0.165); catalogued as COSV65317991; called by muse, mutect2, varscan2
- RAMP2 | c.238G>A p.E80K | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs373990860; called by muse, mutect2, varscan2
- RANBP10 | c.1593G>T p.K531N | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.823); catalogued as COSV100449395; called by mutect2, varscan2
- RANBP3L | c.371G>T p.R124I | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV99683951; called by muse, mutect2, varscan2
- RBBP7 | c.958T>C p.F320L | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as COSV100417961, COSV58112789; called by muse, mutect2, varscan2
- RBM41 | c.590T>C p.I197T | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.071); catalogued as COSV99179815; called by muse, mutect2, varscan2
- RBM48 | c.372A>C p.E124D | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV99720297; called by muse, mutect2, varscan2
- RBM6 | c.302C>T p.S101L | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.223); catalogued as rs777118077, COSV56482029; called by muse, mutect2, varscan2
- RELN | c.6934C>A p.L2312I | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.782); catalogued as COSV58994201; called by muse, mutect2, varscan2
- REV3L | c.9068G>A p.R3023Q | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.52); PolyPhen benign (0.022); catalogued as rs765471595, COSV62619717, COSV62620160, COSV62624431; called by muse, mutect2, varscan2
- REV3L | c.7279C>T p.R2427W | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.042); catalogued as rs1307537252, COSV100725448; called by muse, mutect2, varscan2
- REV3L | c.6493A>C p.K2165Q | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0.08); catalogued as COSV100725449; called by muse, mutect2
- REV3L | c.4594G>T p.E1532* | Nonsense Mutation (SNP) | VAF 20/53 reads (38%) | catalogued as COSV100725451; called by muse, mutect2, varscan2
- REV3L | c.3485C>A p.S1162Y | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.594); catalogued as COSV100725454; called by muse, mutect2, varscan2
- RFPL1 | c.49A>C p.N17H | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.078); catalogued as COSV62977364; called by muse, mutect2, varscan2
- RFPL3 | c.47G>T p.G16V | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.001); catalogued as COSV99967195; called by muse, mutect2, varscan2
- RFTN1 | c.1734C>A p.N578K | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.22); catalogued as COSV100489650; called by muse, mutect2, varscan2
- RGL4 | c.1089G>A p.A363= | Splice Region (SNP) | VAF 10/20 reads (50%) | catalogued as rs527600048, COSV99318676; called by muse, varscan2
- RGS12 | c.2801C>T p.S934L | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs376215961; called by muse, mutect2
- RGS22 | c.375A>C p.K125N | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100693567; called by muse, mutect2, varscan2
- RGS5 | c.135G>T p.E45D | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as COSV100009212; called by muse, mutect2, varscan2
- RHOXF1 | c.531C>A p.D177E | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99483879; called by muse, mutect2, varscan2
- RIOX1 | c.1421G>T p.R474I | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as COSV100408067; called by muse, mutect2, varscan2
- RLF | c.1349C>A p.S450Y | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs765409701, COSV65653099; called by muse, mutect2, varscan2
- RNF133 | c.113G>T p.W38L | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.55); catalogued as COSV100411676; called by muse, mutect2, varscan2
- RNF213 | c.12626C>A p.S4209Y | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.72); PolyPhen possibly damaging (0.659); catalogued as COSV100301138; called by muse, mutect2, varscan2
- RNF214 | c.2072A>G p.N691S | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.37); PolyPhen benign (0.164); catalogued as rs1284418857, COSV100326835; called by muse, mutect2, varscan2
- RP1L1 | c.4841G>A p.R1614Q | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.743); catalogued as rs563706341, COSV66759083; called by muse, mutect2, varscan2
- RP1L1 | c.763C>T p.P255S | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV101223444; called by muse, mutect2, varscan2
- RPGRIP1L | c.1330C>T p.R444C | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.708); catalogued as rs1296403401, COSV50902601; called by muse, mutect2, varscan2
- RPS6KA2 | c.329G>A p.R110K | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV99691592; called by muse, mutect2, varscan2
- RRM2B | c.947C>A p.S316Y | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.938); catalogued as COSV52566316, COSV52567374; called by muse, mutect2, varscan2
- RTL9 | c.599C>A p.S200Y | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.558); catalogued as COSV101511746; called by muse, mutect2, varscan2
- RYR2 | c.3394G>T p.E1132* | Nonsense Mutation (SNP) | VAF 20/50 reads (40%) | catalogued as COSV100772021; called by muse, mutect2, varscan2
- RYR2 | c.11152G>T p.E3718* | Nonsense Mutation (SNP) | VAF 11/20 reads (55%) | catalogued as COSV100771961; called by muse, mutect2, varscan2
- RYR2 | c.12958G>A p.E4320K | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as rs1409819668, COSV63686403; called by muse, mutect2
- RYR3 | c.198C>A p.C66* | Nonsense Mutation (SNP) | VAF 10/40 reads (25%) | catalogued as COSV101213290, COSV66784168; called by muse, mutect2, varscan2
- S1PR3 | c.434C>T p.P145L | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (1); PolyPhen probably damaging (0.999); catalogued as COSV100822581; called by muse, mutect2, varscan2
- SACS | c.12339G>T p.L4113F | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.972); catalogued as COSV101207555; called by muse, mutect2, varscan2
- SAMD3 | c.1336G>A p.E446K | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.424); catalogued as rs144249057; called by muse, mutect2, varscan2
- SAMD9L | c.1454C>A p.S485Y | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.127); catalogued as COSV100560965; called by muse, mutect2, varscan2
- SATB2 | c.862G>T p.A288S | Missense Mutation (SNP) | VAF 76/173 reads (44%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as rs142825652, COSV99612002; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCGB1D1 | c.89A>C p.E30A | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); catalogued as COSV100086770; called by muse, mutect2, varscan2
- SCGN | c.760G>A p.D254N | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776417318, COSV58544866; called by muse, mutect2, varscan2
- SCN1A | c.2802G>T p.M934I (on ENST00000303395 / NM_001202435.3; = p.M923I on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as CM044043, CM044044, COSV57666409, COSV57675630; called by muse, mutect2, varscan2
- SEC16B | c.147G>A p.W49* | Nonsense Mutation (SNP) | VAF 9/73 reads (12%) | catalogued as rs758261941, COSV100381785; called by muse, mutect2, varscan2
- SELENOM | c.307G>A p.E103K | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0.009); catalogued as rs1351095979, COSV60775951; called by muse, mutect2, varscan2
- SELP | c.1285C>T p.R429W | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as rs761957913, COSV55248848; called by muse, mutect2, varscan2
- SEPTIN14 | c.235G>T p.D79Y | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.878); catalogued as COSV101193396, COSV66428430; called by muse, mutect2, varscan2
- SEPTIN4 | c.1350G>T p.E450D | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.885); catalogued as COSV100051251; called by muse, mutect2, varscan2
- SEPTIN4 | c.407G>A p.R136Q | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1428588852, COSV100422100; called by muse, mutect2, varscan2
- SERPINI2 | c.974A>C p.E325A | Missense Mutation (SNP) | VAF 17/30 reads (57%) | SIFT deleterious (0.02); PolyPhen benign (0.419); catalogued as COSV99248156; called by muse, mutect2, varscan2
- SETX | c.1468G>A p.V490I | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs763545230, COSV56387265; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SF3B1 | c.2870G>A p.R957Q | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.897); catalogued as rs773349667, COSV59206258; called by muse, mutect2, varscan2
- SFXN4 | c.952C>A p.L318I | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); catalogued as COSV100341158; called by muse, mutect2, varscan2
- SHPRH | c.394A>C p.N132H | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as rs756413289, COSV99262417; called by muse, mutect2, varscan2
- SHTN1 | c.1316C>T p.S439L | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs772447430, COSV53380035; called by muse, mutect2, varscan2
- SIGLEC6 | c.139G>A p.V47I | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.599); catalogued as COSV58431638; called by muse, mutect2, varscan2
- SIPA1L2 | c.887G>A p.R296Q | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs1299436043, COSV53399158; called by muse, mutect2, varscan2
- SIPA1L3 | c.1524C>A p.F508L | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.385); catalogued as COSV55911769, COSV99729691; called by muse, mutect2, varscan2
- SKIL | c.1026G>T p.K342N | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.762); catalogued as COSV52059066; called by muse, mutect2, varscan2
- SLAMF8 | c.28C>T p.L10F | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.406); catalogued as COSV99223038; called by muse, mutect2, varscan2
- SLAMF8 | c.475G>A p.E159K | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.264); catalogued as rs368997999; called by muse, mutect2, varscan2
- SLC12A1 | c.333G>T p.K111N | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.66); PolyPhen benign (0.015); catalogued as COSV100372448, COSV100372621; called by muse, mutect2, varscan2
- SLC15A3 | c.1318G>A p.E440K | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated (0.96); PolyPhen benign (0.251); catalogued as rs1040401585, COSV50003294; called by muse, mutect2, varscan2
- SLC15A4 | c.975C>G p.F325L | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.534); catalogued as COSV99903697; called by muse, mutect2, varscan2
- SLC17A1 | c.303C>A p.F101L | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99765950; called by muse, varscan2
- SLC17A6 | c.850G>T p.E284* | Nonsense Mutation (SNP) | VAF 25/57 reads (44%) | catalogued as COSV99580623; called by muse, mutect2, varscan2
- SLC17A7 | c.527G>T p.R176M | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV99676972; called by muse, mutect2, varscan2
- SLC18A2 | c.1412G>A p.R471Q | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.545); catalogued as rs1482667636, COSV53689507; called by muse, mutect2, varscan2
- SLC22A25 | c.1433T>C p.I478T | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.43); PolyPhen benign (0.034); catalogued as rs752284959, COSV100123790; called by muse, varscan2
- SLC24A2 | c.129C>A p.F43L | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0); catalogued as COSV99647063; called by muse, mutect2, varscan2
- SLC25A33 | c.595G>A p.E199K | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs544661758, COSV100235826; called by muse, mutect2, varscan2
- SLC25A46 | c.491G>A p.G164E | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV100582633; called by muse, mutect2, varscan2
- SLC34A1 | c.1290C>T p.I430= | Splice Region (SNP) | VAF 8/17 reads (47%) | catalogued as rs774126797, COSV60995780; called by muse, mutect2, varscan2
- SLC35A2 | c.484C>T p.R162C | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV54431177, COSV99504134; called by muse, mutect2, varscan2
- SLC39A12 | c.1318G>T p.E440* | Nonsense Mutation (SNP) | VAF 37/97 reads (38%) | catalogued as COSV101070094, COSV66201781; called by muse, mutect2, varscan2
- SLC4A5 | c.3193G>A p.D1065N | Missense Mutation (SNP) | VAF 14/17 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs760570306, COSV100697407, COSV61027834; called by muse, mutect2, varscan2
- SLC6A19 | c.644G>A p.G215D | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100443635; called by muse, mutect2, varscan2
- SLC6A5 | c.1750G>A p.E584K | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV54225368; called by muse, mutect2, varscan2
- SLC6A7 | c.196C>T p.R66* | Nonsense Mutation (SNP) | VAF 15/50 reads (30%) | catalogued as rs1239391602, COSV57939101; called by muse, mutect2, varscan2
- SLC8A2 | c.454G>A p.G152S | Missense Mutation (SNP) | VAF 13/20 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1470448704, COSV52639393, COSV99369865, COSV99370429; called by muse, mutect2, varscan2
- SLC9C2 | c.3341G>A p.G1114E | Missense Mutation (SNP) | VAF 32/66 reads (48%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.026); catalogued as rs753975075, COSV100876898; called by muse, mutect2, varscan2
- SLCO3A1 | c.1184C>T p.A395V | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.33); catalogued as rs775241468, COSV59230207; called by muse, mutect2, varscan2
- SLCO5A1 | c.496G>A p.E166K | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.967); catalogued as COSV99480523; called by muse, mutect2, varscan2
- SLFN11 | c.2194C>T p.R732C | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.29); catalogued as rs200734680, COSV57698638, COSV57699725; called by muse, mutect2, varscan2
- SLITRK4 | c.1576A>C p.I526L | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as COSV100567437, COSV62024611; called by muse, varscan2
- SMARCA1 | c.286G>T p.E96* | Nonsense Mutation (SNP) | VAF 24/53 reads (45%) | catalogued as COSV100946635; called by muse, mutect2, varscan2
- SMARCA2 | c.1528G>A p.D510N | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100571373; called by muse, mutect2, varscan2
- SMC4 | c.3754C>T p.R1252* | Nonsense Mutation (SNP) | VAF 22/51 reads (43%) | catalogued as rs753471840, COSV59086399; called by muse, mutect2, varscan2
- SNAP25 | c.175C>T p.R59C | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV54775129; called by muse, mutect2, varscan2
- SNCAIP | c.1306C>A p.L436I | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs761349953, COSV54416036; called by muse, mutect2, varscan2
- SNX2 | c.400G>T p.E134* | Nonsense Mutation (SNP) | VAF 20/46 reads (43%) | catalogued as COSV101075780; called by muse, mutect2, varscan2
- SNX32 | c.290C>T p.S97L | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.057); catalogued as rs749832403, COSV100362657; called by muse, mutect2, varscan2
- SORL1 | c.1007G>A p.R336K | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.76); PolyPhen benign (0.006); catalogued as COSV99494741; called by muse, mutect2, varscan2
- SOX6 | c.278G>A p.R93Q | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.195); catalogued as rs148119560, COSV57054947; called by muse, mutect2, varscan2
- SP110 | c.767C>A p.S256Y | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as COSV51250235; called by muse, varscan2
- SPAG17 | c.3913C>A p.L1305I | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1310607429, COSV60452650; called by muse, mutect2, varscan2
- SPATA22 | c.32G>A p.R11Q | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs770870928, COSV99279349; called by muse, varscan2
- SPATA4 | c.367T>A p.F123I | Missense Mutation (SNP) | VAF 23/41 reads (56%) | SIFT tolerated (0.2); PolyPhen benign (0.041); catalogued as COSV54591437; called by muse, mutect2, varscan2
- SPECC1 | c.563G>A p.R188Q | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious (0.02); PolyPhen benign (0.337); catalogued as rs1171933853, COSV99821706; called by muse, mutect2, varscan2
- SPEN | c.9046T>G p.L3016V | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV101005459; called by muse, mutect2, varscan2
- SPOPL | c.96T>G p.F32L | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.453); catalogued as COSV99699621; called by muse, mutect2, varscan2
- SPSB3 | c.305-1G>A p.X102_splice | Splice Site (SNP) | VAF 3/39 reads (8%) | catalogued as COSV51908293; called by muse, mutect2
- SPTA1 | c.13C>T p.P5S | Missense Mutation (SNP) | VAF 36/88 reads (41%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV100935254, COSV63758892; called by muse, mutect2, varscan2
- SPTAN1 | c.5050G>A p.E1684K | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.54); PolyPhen benign (0.13); catalogued as rs1307013962, COSV63989814; called by muse, mutect2, varscan2
- SPTBN5 | c.8587G>A p.D2863N | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.104); catalogued as COSV100311864; called by muse, mutect2, varscan2
- SPZ1 | c.475G>T p.E159* | Nonsense Mutation (SNP) | VAF 10/24 reads (42%) | catalogued as COSV57064578; called by muse, mutect2, varscan2
- SRPRA | c.411G>T p.K137N | Missense Mutation (SNP) | VAF 35/75 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.285); catalogued as COSV55006076, COSV99702914; called by muse, mutect2, varscan2
- SSTR2 | c.825C>A p.F275L | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT tolerated (1); PolyPhen benign (0.028); catalogued as COSV100192140; called by muse, mutect2, varscan2
- SSUH2 | c.575G>T p.R192I | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as COSV100436019; called by muse, mutect2, varscan2
- SSX5 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 29/89 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as COSV100308847; called by muse, mutect2
- STAC | c.907G>T p.D303Y | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99830383; called by muse, mutect2, varscan2
- STAG2 | c.2704G>T p.E902* | Nonsense Mutation (SNP) | VAF 26/69 reads (38%) | catalogued as COSV99494037; called by muse, mutect2, varscan2
- STAG3 | c.515C>T p.S172L | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.274); catalogued as rs774733921, COSV100425739; called by muse, mutect2, varscan2
- STARD8 | c.2281G>A p.A761T | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99367230; called by muse, mutect2, varscan2
- STK17B | c.745C>A p.Q249K | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.329); catalogued as COSV99826204; called by muse, mutect2, varscan2
- STK31 | c.361A>G p.I121V | Missense Mutation (SNP) | VAF 31/60 reads (52%) | SIFT tolerated (0.8); PolyPhen benign (0.416); catalogued as COSV100669717; called by muse, mutect2, varscan2
- STK31 | c.844G>A p.E282K | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.386); catalogued as COSV63454027; called by muse, mutect2, varscan2
- STK33 | c.167C>A p.S56* | Nonsense Mutation (SNP) | VAF 5/60 reads (8%) | catalogued as COSV100174293, COSV59402791; called by muse, mutect2
- STS | c.1054C>A p.H352N | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.21); PolyPhen benign (0.113); catalogued as COSV99481494; called by muse, mutect2, varscan2
- STXBP5L | c.473T>G p.I158S | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99875383; called by muse, mutect2, varscan2
- STXBP6 | c.256C>T p.R86C | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); catalogued as COSV100121844, COSV100122050; called by muse, mutect2, varscan2
- SUPT16H | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 9/22 reads (41%) | catalogued as COSV53522905; called by muse, mutect2, varscan2
- SV2B | c.1336A>C p.N446H | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100370816; called by muse, mutect2, varscan2
- SYNE2 | c.2212G>T p.D738Y | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.365); catalogued as COSV100648161; called by mutect2, varscan2
- SYNE2 | c.10666G>T p.E3556* | Nonsense Mutation (SNP) | VAF 13/31 reads (42%) | catalogued as COSV100648162, COSV59942159; called by muse, mutect2, varscan2
- SYNE3 | c.2631T>G p.D877E | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.19); PolyPhen benign (0.259); catalogued as COSV100516274; called by muse, mutect2, varscan2
- SYTL3 | c.1470G>T p.K490N (on ENST00000611299 / NM_001242394.1; = p.K422N on NM_001009991.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/41 reads (54%) | SIFT deleterious (0.03); PolyPhen benign (0.042); catalogued as COSV51916661; called by muse, mutect2, varscan2
- TAF1L | c.3666G>T p.E1222D | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (0.46); PolyPhen benign (0.005); catalogued as COSV54268867; called by muse, mutect2, varscan2
- TAGAP | c.2182G>T p.E728* | Nonsense Mutation (SNP) | VAF 11/24 reads (46%) | catalogued as COSV100487567; called by muse, mutect2, varscan2
- TANC2 | c.4916C>A p.S1639* | Nonsense Mutation (SNP) | VAF 18/38 reads (47%) | catalogued as rs76448506, COSV101267615; called by muse, mutect2, varscan2
- TBC1D12 | c.1930G>T p.E644* | Nonsense Mutation (SNP) | VAF 15/32 reads (47%) | catalogued as COSV99831653; called by muse, mutect2, varscan2
- TBC1D19 | c.311G>T p.R104I | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV99336171; called by muse, mutect2, varscan2
- TCF21 | c.259C>T p.R87* | Nonsense Mutation (SNP) | VAF 7/25 reads (28%) | catalogued as COSV52818942; called by muse, mutect2, varscan2
- TCF4 | c.989C>T p.S330L | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as CD120294, COSV61906793; called by muse, mutect2, varscan2
- TCP11L2 | c.455G>A p.R152H | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.127); catalogued as rs138884019, COSV54433174; called by muse, mutect2, varscan2
- TCTE1 | c.628G>A p.D210N | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.578); catalogued as COSV65255466, COSV65256127; called by muse, mutect2, varscan2
- TDRD1 | c.2410G>A p.E804K | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99314679; called by muse, mutect2, varscan2
- TDRD6 | c.2759T>G p.L920* | Nonsense Mutation (SNP) | VAF 11/25 reads (44%) | catalogued as COSV100287971; called by muse, mutect2, varscan2
- TDRD7 | c.1027G>T p.E343* | Nonsense Mutation (SNP) | VAF 8/25 reads (32%) | catalogued as COSV100795622; called by muse, mutect2, varscan2
- TEKT3 | c.350C>T p.S117L | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); catalogued as rs376822371; called by muse, mutect2, varscan2
- TENM1 | c.7008G>T p.E2336D | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); catalogued as COSV100950467; called by muse, mutect2, varscan2
- TENM4 | c.5440C>T p.R1814C | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs912426848, COSV53613100; called by muse, mutect2, varscan2
- TESPA1 | c.1181C>A p.S394Y (on ENST00000316577 / NM_001098815.3; = p.S256Y on NM_014796.2 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.005); catalogued as COSV57257735; called by muse, mutect2
- TET2 | c.367C>T p.R123C | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs749710391, COSV54399131, COSV54429506; called by muse, mutect2, varscan2
- TEX14 | c.7C>T p.R3W | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as rs763953318, COSV53630114; called by muse, mutect2, varscan2
- TEX15 | c.7347T>G p.S2449R (on ENST00000256246; = p.S2832R on NM_001350162.2) | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.7); catalogued as COSV99821804; called by muse, mutect2, varscan2
- TEX45 | c.1216T>G p.F406V | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.595); catalogued as COSV100861818; called by muse, mutect2, varscan2
- TFAM | c.394G>T p.E132* | Nonsense Mutation (SNP) | VAF 10/35 reads (29%) | catalogued as COSV100876079; called by muse, mutect2, varscan2
- TFAP2A | c.931G>A p.E311K (on ENST00000482890; = p.E303K on NM_001032280.3) | Missense Mutation (SNP) | VAF 14/22 reads (64%) | SIFT deleterious (0.01); PolyPhen benign (0.265); catalogued as rs756122879, COSV100117071; called by muse, varscan2
- TFAP2D | c.665G>T p.S222I | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99146147; called by muse, mutect2, varscan2
- TFDP3 | c.701G>T p.R234I | Missense Mutation (SNP) | VAF 24/44 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100033451; called by muse, mutect2, varscan2
- TGFB1I1 | c.1182G>T p.E394D (on ENST00000394863 / NM_001042454.3; = p.E377D on NM_015927.4) | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.893); catalogued as COSV62358703; called by muse, mutect2
- THAP12 | c.232C>T p.R78* | Nonsense Mutation (SNP) | VAF 17/44 reads (39%) | catalogued as COSV52610747, COSV99473138; called by muse, mutect2, varscan2
- THBS2 | c.2013C>A p.F671L | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.838); catalogued as COSV100827983; called by muse, mutect2, varscan2
- TIGD4 | c.1514T>G p.F505C | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100428028; called by muse, mutect2, varscan2
- TIMM44 | c.148T>C p.S50P | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.177); catalogued as COSV99564248; called by muse, mutect2, varscan2
- TINAG | c.1099G>T p.E367* | Nonsense Mutation (SNP) | VAF 8/18 reads (44%) | catalogued as rs761456366, COSV52512069, COSV99448132; called by muse, mutect2, varscan2
- TIPIN | c.425G>A p.R142Q | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.283); catalogued as rs76072153, COSV56019977; called by muse, mutect2, varscan2
- TLE4 | c.986G>A p.R329Q | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as COSV54629821, COSV54636157; called by muse, mutect2, varscan2
- TLR10 | c.1599C>A p.F533L | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV100457816, COSV58301213; called by muse, mutect2, varscan2
- TLR3 | c.1612C>A p.Q538K | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); catalogued as COSV99711100; called by muse, mutect2, varscan2
- TLR4 | c.1459T>G p.F487V (on ENST00000355622 / NM_138554.5; = p.F447V on NM_003266.4) | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.33); PolyPhen benign (0.015); catalogued as COSV62923063, COSV62924683; called by muse, mutect2, varscan2
- TLR6 | c.877C>T p.R293C | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.276); catalogued as rs772979516, COSV67935168; called by muse, varscan2
- TLR7 | c.871G>T p.E291* | Nonsense Mutation (SNP) | VAF 15/25 reads (60%) | catalogued as COSV101028010; called by muse, mutect2, varscan2
- TM7SF3 | c.471C>A p.F157L | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100544921; called by muse, mutect2, varscan2
- TM9SF2 | c.1507C>T p.R503* | Nonsense Mutation (SNP) | VAF 24/64 reads (38%) | catalogued as COSV64506554; called by muse, mutect2, varscan2
- TMEM131 | c.271A>T p.S91C | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.322); catalogued as COSV99488793; called by muse, mutect2, varscan2
- TMEM132B | c.3022G>T p.E1008* | Nonsense Mutation (SNP) | VAF 11/25 reads (44%) | catalogued as COSV54753080; called by muse, mutect2, varscan2
- TMEM182 | c.77G>A p.G26E | Missense Mutation (SNP) | VAF 31/63 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV101305401; called by muse, mutect2, varscan2
- TMEM199 | c.167C>A p.S56Y | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.594); catalogued as rs782800509, COSV50228242; called by muse, mutect2, varscan2
- TMF1 | c.1912G>T p.D638Y | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV101275451; called by muse, mutect2, varscan2
- TMPRSS4 | c.644C>A p.S215Y | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.683); catalogued as COSV101449414; called by muse, mutect2, varscan2
- TNIP3 | c.211A>C p.K71Q | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT tolerated (0.37); PolyPhen benign (0.12); catalogued as COSV99284677; called by muse, varscan2
- TNMD | c.741C>A p.D247E | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT tolerated (0.22); PolyPhen benign (0.018); catalogued as COSV100887897; called by muse, mutect2, varscan2
- TOGARAM1 | c.4417C>T p.R1473C | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.702); catalogued as rs772832978, COSV63891985, COSV99053557; called by muse, mutect2, varscan2
- TOLLIP | c.92G>A p.R31Q | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs137869091; called by muse, mutect2, varscan2
- TP53BP2 | c.3271A>C p.T1091P (on ENST00000343537 / NM_001031685.3; = p.T962P on NM_005426.2) | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.695); catalogued as COSV100636727; called by muse, mutect2, varscan2
- TPPP2 | c.188G>A p.R63Q | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.041); catalogued as rs185684452, COSV58794523; called by muse, mutect2, varscan2
- TPTE2 | c.1199G>T p.R400I (on ENST00000400230 / NM_199254.2; = p.R323I on NM_130785.3) | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.251); catalogued as COSV55028843, COSV99690664; called by muse, mutect2, varscan2
- TPTE2 | c.557G>T p.R186I (on ENST00000400230 / NM_199254.2; = p.R109I on NM_130785.3) | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55025003, COSV55028348; called by muse, mutect2, varscan2
- TRABD2A | c.920G>T p.R307I (on ENST00000409520 / NM_001277053.2; = p.R258I on NM_001080824.3) | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100119592; called by mutect2, varscan2
- TRAPPC4 | c.643T>G p.F215V | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.071); catalogued as COSV100421572; called by muse, mutect2, varscan2
329 further variants in this file (102 protein-altering or splice-affecting, 206 silent, 21 other) are not listed here.
